Somatic mutation profile of tumor specimen TCGA-D3-A5GO-06A (aliquot TCGA-D3-A5GO-06A-12D-A27K-08) from TCGA case TCGA-D3-A5GO, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 68.5 years (25,026 days).
Specimen TCGA-D3-A5GO-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0380abd6-c0f5-4b26-b454-e58da88ad080.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D3-A5GO-10A (Blood Derived Normal), aliquot TCGA-D3-A5GO-10A-01D-A27N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1e372b7b-b232-488a-8dd6-6c2aab1774bc

The open-access MAF lists 1,889 somatic variants for this specimen: 1,224 protein-altering or splice-affecting, 624 silent, 41 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,125, Silent 624, Nonsense Mutation 61, Intron 20, Splice Region 17, Splice Site 10, RNA 8, 5'Flank 4, 3'UTR 4, Translation Start Site 3, Frame Shift Ins 3, 3'Flank 3.

Variants (750 of 1,889; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HEPHL1 | c.1063G>A p.A355T | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.596); catalogued as rs774463623, COSV59890284; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KDR | c.3095G>A p.R1032Q | Missense Mutation (SNP) | VAF 42/65 reads (65%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1190050670, COSV55758808; called by muse, mutect2, varscan2
- KLHL41 | c.215dup p.E73Gfs*13 | Frame Shift Ins (INS) | VAF 46/145 reads (32%) | catalogued as rs775513051; ClinVar: pathogenic; called by mutect2, varscan2
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 128/198 reads (65%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.839G>A p.R280K | Missense Mutation (SNP) | VAF 20/25 reads (80%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.925); catalogued as rs121912660, CM153865, CM993218, COSV52666248, COSV52677783, COSV52687987; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- TP63 | c.797G>A p.R266Q | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.92); catalogued as rs121908849, CM013065, CM110083, COSV53200099; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCB5 | c.2489C>T p.S830F (on ENST00000404938 / NM_001163941.2; = p.S385F on NM_178559.6) | Missense Mutation (SNP) | VAF 42/107 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs866781790, COSV51705583; called by muse, mutect2, varscan2
- ABCC1 | c.2750C>T p.S917F | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.284); catalogued as COSV60682351; called by muse, mutect2, varscan2
- ABCC11 | c.3904G>A p.D1302N | Missense Mutation (SNP) | VAF 62/154 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1174748693, COSV62321883; called by muse, varscan2
- ABCC2 | c.2767C>T p.H923Y | Missense Mutation (SNP) | VAF 26/47 reads (55%) | SIFT tolerated (0.75); PolyPhen benign (0.177); catalogued as COSV64985076; called by muse, varscan2
- ABCC4 | c.3248C>T p.S1083F | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV65310671; called by muse, mutect2, varscan2
- ABCC5 | c.1367C>T p.S456F | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.009); catalogued as COSV55588236, COSV55593054; called by muse, mutect2, varscan2
- ABCF1 | c.2125G>A p.E709K (on ENST00000326195 / NM_001025091.2; = p.E671K on NM_001090.3) | Missense Mutation (SNP) | VAF 108/198 reads (55%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); catalogued as COSV58227746; called by muse, mutect2
- AC005833.1 | c.1268C>T p.T423I | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious, low confidence (0); catalogued as COSV99363053; called by muse, mutect2, varscan2
- AC008397.2 | c.328C>T p.P110S | Missense Mutation (SNP) | VAF 31/56 reads (55%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0.003); catalogued as rs758343814, COSV53205473; called by muse, mutect2, varscan2
- ACAN | c.5744G>A p.S1915N | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.995); catalogued as rs781254805, COSV61357705; called by muse, mutect2, varscan2
- ACKR2 | c.357G>A p.M119I | Missense Mutation (SNP) | VAF 57/158 reads (36%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as rs1420218079, COSV56177209; called by muse, mutect2, varscan2
- ACSM4 | c.866G>A p.G289E | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68067131; called by muse, mutect2, varscan2
- ACSS3 | c.1455G>A p.M485I | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT tolerated (0.05); PolyPhen benign (0.054); catalogued as rs989417666, COSV54087157; called by muse, mutect2, varscan2
- ACTN1 | c.2117C>T p.T706I | Missense Mutation (SNP) | VAF 65/80 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs373795472; called by muse, mutect2, varscan2
- ACVRL1 | c.1101C>G p.N367K | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66359771; called by muse, mutect2, varscan2
- ADAM12 | c.758G>A p.R253K | Missense Mutation (SNP) | VAF 16/22 reads (73%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV64103903; called by muse, mutect2, varscan2
- ADAM18 | c.2055G>A p.W685* | Nonsense Mutation (SNP) | VAF 24/66 reads (36%) | catalogued as rs1195296558, COSV55845187; called by muse, mutect2, varscan2
- ADAM2 | c.1706G>A p.G569E | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.759); catalogued as COSV55859996; called by muse, mutect2, varscan2
- ADAM28 | c.228G>A p.K76= | Splice Region (SNP) | VAF 10/32 reads (31%) | catalogued as COSV56098833; called by muse, mutect2, varscan2
- ADAM7 | c.536C>T p.T179I | Missense Mutation (SNP) | VAF 42/109 reads (39%) | SIFT tolerated (0.47); PolyPhen benign (0.057); catalogued as rs868821595, COSV51536734; called by muse, mutect2, varscan2
- ADAMTS13 | c.449C>T p.S150F | Missense Mutation (SNP) | VAF 26/37 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV63020489; called by muse, mutect2, varscan2
- ADAMTS19 | c.1597G>A p.E533K | Missense Mutation (SNP) | VAF 88/182 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.341); catalogued as COSV50735929, COSV99180420; called by muse, mutect2, varscan2
- ADAMTS2 | c.2054C>T p.A685V | Missense Mutation (SNP) | VAF 35/76 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.272); catalogued as COSV52368382; called by muse, mutect2, varscan2
- ADAMTSL3 | c.2121G>A p.W707* | Nonsense Mutation (SNP) | VAF 25/48 reads (52%) | catalogued as COSV54440308; called by muse, mutect2, varscan2
- ADGRE1 | c.1228G>A p.E410K | Missense Mutation (SNP) | VAF 58/151 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.011); catalogued as rs1219606162, COSV51673229; called by muse, mutect2, varscan2
- ADGRL2 | c.2264C>T p.S755L (on ENST00000370717 / NM_001366005.1; = p.S742L on NM_012302.4) | Missense Mutation (SNP) | VAF 30/175 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.347); catalogued as COSV54657880; called by muse, mutect2, varscan2
- ADGRV1 | c.11195C>T p.S3732L | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.201); catalogued as rs1162525847, COSV67980716; called by muse, mutect2, varscan2
- ADGRV1 | c.11819C>T p.P3940L | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.355); catalogued as COSV67980719; called by muse, varscan2
- ADGRV1 | c.11896G>A p.D3966N | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs537561836, COSV67980723; called by muse, varscan2
- ADH7 | c.323C>G p.P108R | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99265371; called by muse, mutect2, varscan2
- ADRA1A | c.887C>T p.S296F | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV52359001; called by muse, mutect2, varscan2
- AFP | c.1012G>A p.D338N | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0.096); catalogued as COSV56924389; called by muse, mutect2, varscan2
- AGK | c.163C>T p.P55S | Missense Mutation (SNP) | VAF 43/89 reads (48%) | SIFT tolerated (0.14); PolyPhen benign (0.018); catalogued as rs867258985, COSV62594002; called by muse, mutect2, varscan2
- AHDC1 | c.268C>G p.R90G | Missense Mutation (SNP) | VAF 28/148 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.018); catalogued as COSV55937419, COSV99899852; called by muse, mutect2
- AHNAK2 | c.14807C>T p.P4936L | Missense Mutation (SNP) | VAF 31/39 reads (79%) | SIFT tolerated (0.34); PolyPhen benign (0.013); catalogued as COSV60910634; called by muse, mutect2, varscan2
- AK7 | c.1258G>A p.E420K | Missense Mutation (SNP) | VAF 21/29 reads (72%) | SIFT tolerated (0.18); PolyPhen benign (0.062); catalogued as COSV50869762; called by muse, mutect2, varscan2
- AKAP13 | c.5974G>A p.V1992M (on ENST00000394518 / NM_007200.5; = p.V1996M on NM_006738.6) | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.112); catalogued as COSV100774218; called by muse, mutect2, varscan2
- AKAP13 | c.5975T>A p.V1992E (on ENST00000394518 / NM_007200.5; = p.V1996E on NM_006738.6) | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.462); catalogued as COSV100774220; called by muse, mutect2, varscan2
- AKAP3 | c.1612C>T p.H538Y | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as COSV57414997; called by muse, mutect2
- AKR1C8P | c.334G>A p.D112N | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.425); catalogued as rs782247954; called by muse, mutect2, varscan2
- ALDH1A2 | c.558G>A p.W186* | Nonsense Mutation (SNP) | VAF 11/38 reads (29%) | catalogued as COSV51078839; called by muse, mutect2, varscan2
- ALDH1L1 | c.524G>A p.G175E | Missense Mutation (SNP) | VAF 51/128 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.906); catalogued as rs762085301, COSV56412023; called by muse, mutect2, varscan2
- ALG11 | c.598C>T p.P200S | Missense Mutation (SNP) | VAF 59/123 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101584369, COSV73000811; called by muse, mutect2, varscan2
- ALK | c.1271A>G p.N424S | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.111); catalogued as COSV66561448; called by muse, mutect2, varscan2
- ALOX5 | c.981G>A p.Q327= | Splice Region (SNP) | VAF 23/33 reads (70%) | catalogued as COSV65551604; called by muse, mutect2, varscan2
- ALPK2 | c.5015C>T p.P1672L | Missense Mutation (SNP) | VAF 34/95 reads (36%) | SIFT tolerated (0.25); PolyPhen benign (0.021); catalogued as COSV64493204; called by mutect2, varscan2
- ALPK2 | c.5014C>T p.P1672S | Missense Mutation (SNP) | VAF 35/100 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.063); catalogued as COSV100864580, COSV100864873; called by muse, mutect2, varscan2
- ALPK3 | c.2611C>T p.P871S | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.01); catalogued as rs1439652574, COSV51931142; called by muse, mutect2, varscan2
- ALX3 | c.659G>A p.G220E | Missense Mutation (SNP) | VAF 22/126 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0.273); catalogued as rs1335385096, COSV63928636; called by muse, mutect2, varscan2
- AMER1 | c.2840C>T p.S947F | Missense Mutation (SNP) | VAF 14/22 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV57656670; called by muse, mutect2, varscan2
- AMPH | c.1282G>A p.E428K | Missense Mutation (SNP) | VAF 28/147 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.084); catalogued as COSV57736669; called by muse, mutect2, varscan2
- AMY1C | c.879G>A p.K293= | Splice Region (SNP) | VAF 87/282 reads (31%) | catalogued as COSV64407220; called by muse, varscan2
- ANGPT1 | c.1454C>T p.S485F | Missense Mutation (SNP) | VAF 55/120 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52434149; called by muse, mutect2, varscan2
- ANGPT4 | c.1220+1G>A p.X407_splice | Splice Site (SNP) | VAF 9/33 reads (27%) | catalogued as COSV67920988; called by muse, mutect2, varscan2
- ANK2 | c.6127C>T p.Q2043* | Nonsense Mutation (SNP) | VAF 66/110 reads (60%) | catalogued as COSV52151554; called by muse, mutect2, varscan2
- ANK3 | c.10309C>T p.Q3437* | Nonsense Mutation (SNP) | VAF 32/48 reads (67%) | catalogued as COSV55049044; called by muse, mutect2, varscan2
- ANK3 | c.1954G>A p.E652K | Missense Mutation (SNP) | VAF 28/41 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55049050; called by muse, mutect2, varscan2
- ANK3 | c.1708C>T p.H570Y | Missense Mutation (SNP) | VAF 9/14 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55049069; called by muse, mutect2, varscan2
- ANKK1 | c.2161C>T p.Q721* | Nonsense Mutation (SNP) | VAF 8/28 reads (29%) | catalogued as COSV58270878; called by muse, mutect2
- ANKRD12 | c.5291C>T p.S1764F | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.406); catalogued as COSV50820596; called by muse, mutect2, varscan2
- ANKRD30A | c.1136G>A p.R379K (on ENST00000611781; = p.R323K on NM_052997.2) | Missense Mutation (SNP) | VAF 47/84 reads (56%) | SIFT tolerated (0.39); PolyPhen benign (0.067); catalogued as COSV64606501; called by muse, mutect2, varscan2
- ANKRD35 | c.628G>A p.A210T | Missense Mutation (SNP) | VAF 89/127 reads (70%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100841879, COSV62909857; called by muse, mutect2, varscan2
- ANKS6 | c.994C>G p.L332V | Missense Mutation (SNP) | VAF 41/51 reads (80%) | SIFT tolerated (0.1); PolyPhen benign (0.315); catalogued as rs1398457700, COSV62049431; called by muse, mutect2, varscan2
- ANO3 | c.368G>A p.R123Q | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as rs1254525478, COSV56784546; called by muse, mutect2, varscan2
- ANO5 | c.43G>A p.E15K | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT tolerated, low confidence (0.93); PolyPhen benign (0); catalogued as COSV61082947; called by muse, mutect2
- ANOS1 | c.1357C>T p.P453S | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV52917216; called by muse, mutect2
- AOC1 | c.1028G>A p.G343E | Missense Mutation (SNP) | VAF 47/101 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.16); catalogued as COSV62867500, COSV62868786; called by muse, mutect2, varscan2
- AP001781.2 | c.2T>A p.M1? | Translation Start Site (SNP) | VAF 24/63 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.125); catalogued as COSV52787476; called by muse, mutect2, varscan2
- AP3B2 | c.1982G>A p.W661* | Nonsense Mutation (SNP) | VAF 4/10 reads (40%) | catalogued as COSV55607556; called by muse, mutect2
- APBB2 | c.322C>T p.R108C | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1408680059, COSV55949023; called by muse, mutect2, varscan2
- APOA4 | c.628G>A p.V210I | Missense Mutation (SNP) | VAF 89/226 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.373); catalogued as COSV63360191; called by muse, mutect2, varscan2
- APOB | c.6905G>A p.G2302E | Missense Mutation (SNP) | VAF 40/100 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV51927945, COSV51929374; called by muse, mutect2, varscan2
- ARFGAP1 | c.884C>T p.S295L | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.158); catalogued as rs200768802, COSV62262582; called by muse, mutect2, varscan2
- ARHGAP30 | c.2030G>A p.G677E | Missense Mutation (SNP) | VAF 162/230 reads (70%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.454); catalogued as rs772215293, COSV63515341; called by muse, mutect2, varscan2
- ARHGAP44 | c.2302G>A p.E768K | Missense Mutation (SNP) | VAF 22/37 reads (59%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.971); catalogued as rs77850388, COSV52390882; called by muse, mutect2, varscan2
- ARHGAP45 | c.386G>A p.G129D | Missense Mutation (SNP) | VAF 46/104 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.039); catalogued as COSV54026147; called by muse, mutect2, varscan2
- ARHGEF37 | c.503C>T p.P168L | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV61368233; called by muse, mutect2, varscan2
- ARHGEF5 | c.1055C>T p.S352L | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.175); catalogued as rs1283239137, COSV99283041; called by muse, mutect2, varscan2
- ARHGEF5 | c.3170C>T p.A1057V | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.024); catalogued as COSV99283045; called by mutect2, varscan2
- ARID5B | c.3286C>T p.P1096S | Missense Mutation (SNP) | VAF 6/79 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.647); catalogued as COSV54416483; called by muse, mutect2
- ARMC4 | c.2485G>A p.E829K | Missense Mutation (SNP) | VAF 26/45 reads (58%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.719); catalogued as COSV59459127; called by muse, mutect2, varscan2
- ARMC4 | c.688G>A p.E230K | Missense Mutation (SNP) | VAF 18/27 reads (67%) | SIFT tolerated (0.15); PolyPhen benign (0.164); catalogued as rs867782052, COSV53463722; called by muse, mutect2, varscan2
- ARMCX5-GPRASP2 | c.1133C>T p.S378F | Missense Mutation (SNP) | VAF 23/24 reads (96%) | SIFT tolerated (0.09); PolyPhen benign (0.047); catalogued as rs779461531, COSV63437311; called by muse, mutect2, varscan2
- ARNT2 | c.871C>T p.P291S | Missense Mutation (SNP) | VAF 62/114 reads (54%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.914); catalogued as COSV57582791, COSV57591217; called by muse, mutect2, varscan2
- ARSJ | c.1199G>A p.G400D | Missense Mutation (SNP) | VAF 108/165 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59537114; called by muse, mutect2, varscan2
- ASIC2 | c.1075C>T p.L359F | Missense Mutation (SNP) | VAF 44/104 reads (42%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as COSV56756627, COSV56757795; called by muse, mutect2, varscan2
- ASTN1 | c.1271G>A p.G424E | Missense Mutation (SNP) | VAF 31/52 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as rs766215403, COSV56064465, COSV99920839; called by muse, mutect2
- ASXL3 | c.596G>A p.G199E | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52460830; called by muse, mutect2, varscan2
- ATAD3A | c.856C>T p.R286C | Missense Mutation (SNP) | VAF 78/109 reads (72%) | SIFT deleterious (0.04); PolyPhen benign (0.022); catalogued as rs368185567, COSV59235816; called by muse, mutect2, varscan2
- ATG2A | c.3073G>A p.E1025K | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.551); catalogued as COSV65966143, COSV65968361; called by muse, mutect2, varscan2
- ATP1A3 | c.814C>T p.R272C (on ENST00000545399 / NM_001256214.2; = p.R259C on NM_152296.5) | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100132432; called by muse, mutect2, varscan2
- ATP4A | c.1747G>A p.D583N | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT tolerated (0.25); PolyPhen benign (0.078); catalogued as rs200791532, COSV52866645; called by muse, mutect2, varscan2
- ATP6V0A4 | c.244G>A p.E82K | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT tolerated (0.44); PolyPhen benign (0.12); catalogued as rs929483161; called by muse, varscan2
- ATP7A | c.551C>T p.S184L | Missense Mutation (SNP) | VAF 109/130 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58443938; called by muse, mutect2, varscan2
- ATP9A | c.1372G>A p.E458K | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as rs767492582, COSV58764411; called by muse, mutect2, varscan2
- ATRNL1 | c.3569C>T p.S1190F | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV58078527; called by muse, mutect2, varscan2
- ATXN2L | c.3139C>T p.R1047C | Missense Mutation (SNP) | VAF 65/155 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs1364019012, COSV57367575; called by muse, mutect2, varscan2
- AXDND1 | c.1909G>A p.E637K | Missense Mutation (SNP) | VAF 36/57 reads (63%) | SIFT tolerated (0.55); PolyPhen benign (0.005); catalogued as COSV62640742; called by muse, mutect2, varscan2
- BAALC | c.284T>G p.L95R (on ENST00000297574 / NM_001364874.1; = p.L60R on NM_024812.3) | Missense Mutation (SNP) | VAF 37/117 reads (32%) | SIFT tolerated (0.77); PolyPhen benign (0.112); catalogued as COSV52560929; called by muse, mutect2, varscan2
- BAP1 | c.1885C>T p.P629S | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.223); catalogued as CD117952, COSV56231933; called by muse, mutect2, varscan2
- BAZ2A | c.509C>T p.S170F | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs868319675, COSV51633521; called by muse, mutect2
- BCL11B | c.2098G>A p.A700T (on ENST00000357195 / NM_001282237.2; = p.A629T on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/40 reads (70%) | SIFT tolerated (0.42); PolyPhen benign (0.037); catalogued as rs1211795638, COSV61734496; called by muse, mutect2, varscan2
- BCL6B | c.1258C>T p.R420C | Missense Mutation (SNP) | VAF 41/58 reads (71%) | SIFT deleterious (0); PolyPhen benign (0.047); catalogued as rs750470292, COSV53426802; called by muse, mutect2, varscan2
- BCOR | c.253C>T p.P85S | Missense Mutation (SNP) | VAF 17/26 reads (65%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as COSV60702960; called by muse, mutect2, varscan2
- BCR | c.1697C>T p.P566L | Missense Mutation (SNP) | VAF 45/108 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59928467; called by muse, mutect2, varscan2
- BLMH | c.1114C>T p.H372Y | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55584705; called by muse, mutect2, varscan2
- BMP5 | c.962G>A p.R321Q | Missense Mutation (SNP) | VAF 52/90 reads (58%) | SIFT tolerated (0.45); PolyPhen benign (0.011); catalogued as rs866784947, COSV63701354; called by muse, varscan2
- BMPER | c.1055G>A p.G352E | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.46); catalogued as COSV51813906, COSV51817713; called by muse, mutect2, varscan2
- BPIFB2 | c.182G>A p.G61E | Missense Mutation (SNP) | VAF 30/123 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.071); catalogued as COSV50063446; called by muse, mutect2, varscan2
- BPIFB6 | c.959C>T p.P320L | Missense Mutation (SNP) | VAF 38/212 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.046); catalogued as COSV62754620; called by muse, mutect2, varscan2
- BRD8 | c.1775C>T p.P592L (on ENST00000254900 / NM_139199.2; = p.P665L on NM_006696.4) | Missense Mutation (SNP) | VAF 35/91 reads (38%) | SIFT tolerated (0.71); PolyPhen benign (0.01); catalogued as COSV50146003; called by muse, mutect2, varscan2
- BRINP3 | c.1491G>A p.M497I | Missense Mutation (SNP) | VAF 156/233 reads (67%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV66516979, COSV66528956; called by muse, mutect2, varscan2
- BTF3 | c.572C>T p.P191L (on ENST00000380591 / NM_001037637.1; = p.P147L on NM_001207.4) | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT tolerated (0.08); PolyPhen benign (0.085); catalogued as rs1369153040, COSV59964437; called by muse, mutect2, varscan2
- BTNL2 | c.160C>T p.P54S | Missense Mutation (SNP) | VAF 46/143 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV66630413; called by muse, mutect2, varscan2
- C10orf71 | c.446C>T p.S149F | Missense Mutation (SNP) | VAF 30/43 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV60505727; called by muse, mutect2, varscan2
- C1QTNF7 | c.677G>A p.G226E | Missense Mutation (SNP) | VAF 94/143 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770797389, COSV54851238; called by muse, mutect2, varscan2
- C1QTNF9B | c.536G>A p.G179E | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65943938; called by muse, mutect2, varscan2
- C1S | c.650C>T p.T217I | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.348); catalogued as COSV61070378; called by muse, mutect2, varscan2
- C2CD3 | c.5384C>T p.S1795F | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.066); catalogued as COSV58091125; called by muse, mutect2, varscan2
- C2orf78 | c.1301G>A p.G434E | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (0.35); PolyPhen benign (0.124); catalogued as rs1440190965, COSV68516608; called by muse, mutect2, varscan2
- C3 | c.3154G>A p.G1052R | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55569942, COSV99837016; called by muse, mutect2, varscan2
- C3 | c.3153G>A p.K1051= | Splice Region (SNP) | VAF 13/47 reads (28%) | catalogued as rs570927575, COSV99837020; called by muse, mutect2, varscan2
- C3 | c.1482C>T p.I494= | Splice Region (SNP) | VAF 17/45 reads (38%) | catalogued as COSV55570436; called by muse, mutect2, varscan2
- C3orf20 | c.2386C>T p.R796C | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs190398751, COSV53783377; called by muse, mutect2, varscan2
- C3orf33 | c.871C>T p.R291C (on ENST00000340171 / NM_001308229.2; = p.R248C on NM_173657.2) | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.011); catalogued as rs200965203; called by muse, mutect2, varscan2
- C3orf38 | c.631C>T p.L211F | Missense Mutation (SNP) | VAF 40/112 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); catalogued as COSV59627769, COSV59628542; called by muse, mutect2, varscan2
- C4A | c.3365C>T p.P1122L | Missense Mutation (SNP) | VAF 34/178 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71177579; called by muse, mutect2, varscan2
- C5AR1 | c.848C>T p.S283F | Missense Mutation (SNP) | VAF 47/99 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as COSV61892288; called by muse, mutect2, varscan2
- C6 | c.2611G>A p.E871K | Missense Mutation (SNP) | VAF 89/302 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs865941754, COSV54707096; called by muse, mutect2, varscan2
- C6 | c.1432G>A p.E478K | Missense Mutation (SNP) | VAF 44/149 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.16); catalogued as rs866430363, COSV54704541; called by muse, mutect2, varscan2
- C7 | c.239C>T p.P80L | Missense Mutation (SNP) | VAF 37/145 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57472311; called by muse, mutect2, varscan2
- C8orf34 | c.904G>A p.E302K | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.295); catalogued as COSV61374150; called by muse, mutect2, varscan2
- C9 | c.643G>A p.E215K | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.977); catalogued as rs956317953, COSV54675232, COSV54676962; called by muse, mutect2, varscan2
- CA10 | c.896C>T p.T299I | Missense Mutation (SNP) | VAF 42/85 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV53342331; called by muse, mutect2, varscan2
- CA5A | c.383A>T p.Q128L | Missense Mutation (SNP) | VAF 63/152 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs760098830, COSV59239655; called by muse, mutect2, varscan2
- CABIN1 | c.2203G>T p.E735* | Nonsense Mutation (SNP) | VAF 17/47 reads (36%) | catalogued as COSV54079361; called by muse, mutect2, varscan2
- CACHD1 | c.2566C>T p.P856S | Missense Mutation (SNP) | VAF 40/233 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV51550166; called by muse, mutect2, varscan2
- CACNA1C | c.3821A>T p.K1274I | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59704296; called by muse, mutect2, varscan2
- CACNA1E | c.3423G>A p.P1141= | Splice Region (SNP) | VAF 6/90 reads (7%) | catalogued as COSV100703915; called by muse, mutect2
- CACNA1E | c.4060C>T p.H1354Y | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62385710; called by muse, mutect2, varscan2
- CACNA2D3 | c.2249A>T p.D750V | Missense Mutation (SNP) | VAF 44/114 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.147); catalogued as COSV55523255; called by muse, mutect2, varscan2
- CACNA2D4 | c.1869G>A p.M623I | Missense Mutation (SNP) | VAF 18/30 reads (60%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV54946958; called by muse, mutect2, varscan2
- CADM4 | c.559C>T p.R187C | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.567); catalogued as rs1041418302, COSV55928338; called by muse, mutect2, varscan2
- CADPS2 | c.2365G>A p.D789N | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV57354809; called by muse, mutect2, varscan2
- CALCB | c.227C>T p.S76F | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.023); catalogued as COSV60834267; called by muse, mutect2, varscan2
- CALCR | c.134G>A p.R45Q | Missense Mutation (SNP) | VAF 55/152 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.112); catalogued as rs773160307, COSV64006673; called by muse, mutect2, varscan2
- CAND2 | c.1870G>A p.E624K (on ENST00000456430 / NM_001162499.2; = p.E531K on NM_012298.3) | Missense Mutation (SNP) | VAF 62/189 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55988063; called by muse, mutect2, varscan2
- CAPN13 | c.109G>T p.D37Y | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54429296, COSV54432757; called by muse, mutect2
- CAPNS1 | c.433C>T p.R145C | Missense Mutation (SNP) | VAF 70/150 reads (47%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs200391065, COSV55822491, COSV55823919; called by muse, mutect2, varscan2
- CASP8AP2 | c.1724C>T p.S575F | Missense Mutation (SNP) | VAF 11/16 reads (69%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.461); catalogued as COSV52745870; called by muse, mutect2, varscan2
- CASR | c.1250C>T p.S417F | Missense Mutation (SNP) | VAF 34/81 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.237); catalogued as CM145982, COSV56135468; called by muse, mutect2, varscan2
- CASR | c.2870G>A p.G957E (on ENST00000490131; = p.G1034E on NM_000388.4) | Missense Mutation (SNP) | VAF 35/89 reads (39%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as COSV56135476; called by muse, mutect2, varscan2
- CASZ1 | c.2777C>T p.S926F | Missense Mutation (SNP) | VAF 32/54 reads (59%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.029); catalogued as COSV59733311; called by muse, mutect2, varscan2
- CATSPERD | c.286C>T p.P96S | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as COSV67534140; called by muse, mutect2
- CBY2 | c.757G>A p.E253K | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.994); catalogued as COSV60117578; called by muse, mutect2, varscan2
- CCDC136 | c.1060C>T p.R354W | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775126730, COSV52797544; called by muse, mutect2, varscan2
- CCDC150 | c.2296G>A p.E766K | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.851); catalogued as COSV55872831; called by muse, mutect2, varscan2
- CCDC174 | c.1325C>T p.P442L | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.079); catalogued as COSV53783365; called by muse, mutect2, varscan2
- CCDC184 | c.370G>A p.G124R | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.403); catalogued as COSV57251746; called by muse, mutect2, varscan2
- CCDC33 | c.1048G>A p.D350N | Missense Mutation (SNP) | VAF 61/106 reads (58%) | SIFT deleterious (0.04); PolyPhen benign (0.013); catalogued as COSV58349324; called by muse, mutect2, varscan2
- CCDC33 | c.2042G>A p.R681Q | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs767348207, COSV51431132; called by muse, mutect2, varscan2
- CCDC60 | c.1015G>A p.E339K | Missense Mutation (SNP) | VAF 40/142 reads (28%) | SIFT tolerated (0.37); PolyPhen benign (0.167); catalogued as rs1297066120, COSV59540844; called by muse, mutect2, varscan2
- CCDC70 | c.485G>A p.G162E | Missense Mutation (SNP) | VAF 41/157 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54429935; called by muse, mutect2, varscan2
- CCDC77 | c.1022C>T p.A341V | Missense Mutation (SNP) | VAF 42/64 reads (66%) | SIFT tolerated (0.32); PolyPhen benign (0.015); catalogued as COSV53472272; called by muse, mutect2, varscan2
- CCDC77 | c.1132C>T p.R378C | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as rs1030728081, COSV53472282, COSV53472571; called by muse, mutect2, varscan2
- CCDC88C | c.3115G>A p.E1039K | Missense Mutation (SNP) | VAF 37/48 reads (77%) | SIFT tolerated (0.06); PolyPhen benign (0.071); catalogued as COSV66235613; called by muse, mutect2, varscan2
- CCDC88C | c.1958C>T p.S653F | Missense Mutation (SNP) | VAF 14/19 reads (74%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); catalogued as rs886916252, COSV66241642; called by muse, mutect2, varscan2
- CCHCR1 | c.962C>T p.S321F | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.526); catalogued as COSV66183171; called by muse, mutect2, varscan2
- CCND2 | c.817G>A p.D273N | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.005); catalogued as COSV54222250; called by muse, mutect2
- CCNL2 | c.256C>T p.Q86* | Nonsense Mutation (SNP) | VAF 29/34 reads (85%) | catalogued as rs1360261642, COSV61224049; called by muse, mutect2, varscan2
- CCT8 | c.655C>G p.H219D | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.216); catalogued as COSV54503367; called by muse, mutect2, varscan2
- CD109 | c.1945G>A p.D649N | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.062); catalogued as rs1464432573, COSV54646880; called by muse, mutect2, varscan2
- CD163L1 | c.1237C>T p.P413S | Missense Mutation (SNP) | VAF 47/102 reads (46%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.975); catalogued as COSV58013045; called by muse, mutect2, varscan2
- CD84 | c.304G>A p.E102K | Missense Mutation (SNP) | VAF 158/245 reads (64%) | SIFT tolerated (0.06); PolyPhen benign (0.289); catalogued as COSV100245840, COSV60867252; called by muse, mutect2, varscan2
- CDH10 | c.1913G>A p.R638Q | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.532); catalogued as rs1402706331, COSV52570966, COSV52580434; called by muse, mutect2, varscan2
- CDH10 | c.1738G>A p.G580S | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT tolerated (0.8); PolyPhen benign (0.187); catalogued as COSV52571494, COSV52574272; called by muse, mutect2, varscan2
- CDH10 | c.1172T>G p.F391C | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.092); catalogued as COSV52574280; called by muse, mutect2, varscan2
- CDH16 | c.1306G>A p.E436K | Missense Mutation (SNP) | VAF 39/81 reads (48%) | SIFT tolerated (0.14); PolyPhen benign (0.097); catalogued as rs1165275272, COSV55335574, COSV55340120; called by muse, mutect2, varscan2
- CDH18 | c.574G>A p.G192R | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1435187891, COSV56909108; called by muse, mutect2, varscan2
- CDH19 | c.416C>T p.S139L | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs768597117, COSV50954841; called by muse, mutect2, varscan2
- CDH4 | c.1198G>A p.E400K | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs370373224, COSV100848646; called by muse, mutect2, varscan2
- CDH6 | c.398G>A p.R133K | Missense Mutation (SNP) | VAF 46/173 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.031); catalogued as COSV54066369; called by muse, mutect2, varscan2
- CDH6 | c.562G>A p.D188N | Missense Mutation (SNP) | VAF 33/107 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54066377; called by muse, mutect2, varscan2
- CDH6 | c.1571C>T p.S524L | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT tolerated (0.31); PolyPhen benign (0.066); catalogued as rs202247793, COSV54065357; called by muse, mutect2, varscan2
- CDH7 | c.2231C>T p.S744L | Missense Mutation (SNP) | VAF 31/110 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV59883171; called by muse, mutect2, varscan2
- CDH8 | c.2164G>A p.D722N | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.5); catalogued as rs374778365; called by muse, mutect2, varscan2
- CDH8 | c.328C>T p.Q110* | Nonsense Mutation (SNP) | VAF 24/51 reads (47%) | catalogued as rs267604590, COSV100182320, COSV54846997; called by muse, mutect2, varscan2
- CDK12 | c.2377G>T p.V793F | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV70999753; called by muse, mutect2
- CDK8 | c.373C>T p.R125W | Missense Mutation (SNP) | VAF 16/26 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as COSV67419693; called by muse, mutect2, varscan2
- CDX4 | c.186G>A p.M62I | Missense Mutation (SNP) | VAF 21/24 reads (88%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as COSV65171509; called by muse, mutect2, varscan2
- CEACAM21 | c.293G>A p.R98Q | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.835); catalogued as rs981984811, COSV51813353; called by muse, mutect2, varscan2
- CEACAM4 | c.670-1G>A p.X224_splice | Splice Site (SNP) | VAF 33/88 reads (38%) | catalogued as COSV55730673, COSV99701136; called by muse, mutect2, varscan2
- CEP250 | c.5260C>T p.Q1754* | Nonsense Mutation (SNP) | VAF 51/161 reads (32%) | catalogued as COSV61168759; called by muse, mutect2, varscan2
- CEP250 | c.5953C>T p.L1985F | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.859); catalogued as COSV61168766; called by muse, mutect2, varscan2
- CEP63 | c.1793C>T p.P598L | Missense Mutation (SNP) | VAF 76/178 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.398); catalogued as rs749141478, COSV59674986; called by muse, mutect2, varscan2
- CEP89 | c.109C>T p.P37S | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV59862860, COSV59866359; called by muse, mutect2, varscan2
- CERKL | c.1446C>T p.F482= (on ENST00000339098 / NM_001030311.2; = p.F456= on NM_201548.5) | Splice Region (SNP) | VAF 19/40 reads (48%) | catalogued as COSV59204972; called by muse, mutect2, varscan2
- CERKL | c.1124C>T p.A375V (on ENST00000339098 / NM_001030311.2; = p.A349V on NM_201548.5) | Missense Mutation (SNP) | VAF 35/78 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59204987; called by muse, mutect2, varscan2
- CERT1 | c.1987C>T p.H663Y (on ENST00000405807 / NM_001130105.1; = p.H535Y on NM_005713.3) | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.954); catalogued as COSV54656606; called by muse, mutect2, varscan2
- CFAP298-TCP10L | c.902G>A p.G301E | Missense Mutation (SNP) | VAF 39/97 reads (40%) | SIFT tolerated, low confidence (0.16); PolyPhen possibly damaging (0.712); catalogued as COSV55828580; called by muse, mutect2, varscan2
- CFAP54 | c.7405G>A p.E2469K | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.59); PolyPhen benign (0.062); catalogued as COSV61571234, COSV61572718; called by muse, mutect2, varscan2
- CFHR5 | c.1358C>T p.P453L | Missense Mutation (SNP) | VAF 26/160 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779489184, COSV56819404; called by muse, mutect2, varscan2
- CFL1 | c.331C>T p.L111F | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.968); catalogued as COSV57378889; called by muse, mutect2, varscan2
- CFTR | c.2476G>A p.E826K | Missense Mutation (SNP) | VAF 29/58 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as rs397508381, CM980350, COSV50043996; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CGREF1 | c.704C>T p.A235V | Missense Mutation (SNP) | VAF 97/339 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0.043); catalogued as COSV53148967, COSV53151716; called by muse, varscan2
- CHD6 | c.4454C>T p.S1485F | Missense Mutation (SNP) | VAF 87/231 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV64688994; called by muse, mutect2, varscan2
- CHD7 | c.6368C>T p.S2123F | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV71107906; called by muse, mutect2, varscan2
- CHMP7 | c.433C>T p.P145S | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.164); catalogued as COSV57532559; called by muse, mutect2, varscan2
- CHRM2 | c.95C>T p.S32F | Missense Mutation (SNP) | VAF 32/102 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.087); catalogued as COSV57767767; called by muse, mutect2, varscan2
- CHRNA7 | c.1031G>A p.R344Q | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.948); catalogued as rs761782025, COSV100181219; called by mutect2, varscan2
- CIB3 | c.413G>A p.G138E | Missense Mutation (SNP) | VAF 39/99 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs532690999, COSV54165668; called by muse, mutect2, varscan2
- CIP2A | c.887C>T p.S296F | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.509); catalogued as COSV99843051; called by muse, mutect2, varscan2
- CLCN7 | c.757T>C p.S253P | Missense Mutation (SNP) | VAF 40/78 reads (51%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.983); catalogued as COSV51969412; called by muse, mutect2, varscan2
- CLPP | c.746C>T p.P249L | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.503); catalogued as rs1332188896, COSV55534242; called by muse, mutect2, varscan2
- CLSTN2 | c.2611G>A p.E871K | Missense Mutation (SNP) | VAF 51/138 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.551); catalogued as COSV71719101; called by muse, mutect2, varscan2
- CNGB3 | c.145G>A p.E49K | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.968); catalogued as rs905033514, COSV60686519; called by muse, mutect2, varscan2
- CNIH3 | c.139C>T p.P47S | Missense Mutation (SNP) | VAF 17/110 reads (15%) | SIFT tolerated (0.91); PolyPhen benign (0.219); catalogued as COSV55273118; called by muse, mutect2, varscan2
- CNMD | c.634G>A p.E212K | Missense Mutation (SNP) | VAF 30/89 reads (34%) | SIFT tolerated (0.97); PolyPhen benign (0.009); catalogued as COSV65032651; called by muse, mutect2, varscan2
- CNOT7 | c.82C>T p.R28C | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.146); catalogued as COSV61352502; called by muse, mutect2, varscan2
- CNR2 | c.879G>A p.M293I | Missense Mutation (SNP) | VAF 15/113 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.309); catalogued as COSV65692404; called by muse, mutect2, varscan2
- CNTN5 | c.2949G>A p.W983* | Nonsense Mutation (SNP) | VAF 46/128 reads (36%) | catalogued as COSV54291781; called by muse, mutect2, varscan2
- CNTN5 | c.3154G>A p.G1052R | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1244431152, COSV54291800; called by muse, mutect2, varscan2
- CNTN6 | c.238G>A p.D80N | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT tolerated (0.64); PolyPhen benign (0.258); catalogued as COSV63165681; called by muse, mutect2, varscan2
- CNTN6 | c.2422G>A p.G808R | Missense Mutation (SNP) | VAF 92/225 reads (41%) | SIFT tolerated (0.96); PolyPhen probably damaging (1); catalogued as rs1005325666, COSV63165689; called by muse, mutect2, varscan2
- CNTNAP2 | c.256C>T p.Q86* | Nonsense Mutation (SNP) | VAF 26/75 reads (35%) | catalogued as COSV62156912; called by muse, mutect2, varscan2
- COL19A1 | c.595G>A p.E199K | Missense Mutation (SNP) | VAF 44/85 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.053); catalogued as COSV59568289; called by muse, mutect2, varscan2
- COL1A1 | c.1415G>A p.R472Q | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as rs1362175682, COSV56803228; called by muse, mutect2, varscan2
- COL21A1 | c.2327G>A p.G776E | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55156829; called by muse, varscan2
- COL21A1 | c.2255G>A p.G752E | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55156860; called by muse, varscan2
- COL2A1 | c.4204G>A p.E1402K | Missense Mutation (SNP) | VAF 33/66 reads (50%) | SIFT tolerated (0.09); PolyPhen benign (0.196); catalogued as rs759583931, COSV61528864; called by muse, mutect2, varscan2
- COL3A1 | c.2243G>A p.G748D | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT tolerated (0.44); PolyPhen benign (0.014); catalogued as COSV58584208; called by muse, mutect2, varscan2
- COL4A3 | c.4442G>A p.R1481Q | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT tolerated (0.29); PolyPhen benign (0.026); catalogued as rs768203978, COSV67413959; called by muse, mutect2, varscan2
- COL5A2 | c.1999G>A p.E667K | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.506); catalogued as COSV66408095, COSV66408508; called by muse, mutect2, varscan2
- CORO6 | c.307G>A p.D103N | Missense Mutation (SNP) | VAF 54/134 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1485148160, COSV61470344, COSV61470588; called by muse, mutect2, varscan2
- CPA5 | c.254C>T p.P85L | Missense Mutation (SNP) | VAF 69/155 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV62569080; called by muse, mutect2, varscan2
- CPA6 | c.599G>A p.W200* | Nonsense Mutation (SNP) | VAF 27/63 reads (43%) | catalogued as COSV52722060; called by muse, mutect2, varscan2
- CPED1 | c.1478G>A p.G493E | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT tolerated (0.61); PolyPhen benign (0.005); catalogued as COSV59997102; called by muse, mutect2, varscan2
- CPLX2 | c.310G>A p.G104S | Missense Mutation (SNP) | VAF 21/35 reads (60%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as rs1353969593, COSV63999893; called by muse, mutect2, varscan2
- CPS1 | c.2177C>T p.A726V | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51804951; called by muse, mutect2, varscan2
- CR1L | c.209C>T p.S70F | Missense Mutation (SNP) | VAF 21/186 reads (11%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV54323619; called by muse, mutect2, varscan2
- CRB1 | c.1463T>A p.F488Y | Missense Mutation (SNP) | VAF 53/76 reads (70%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as CM056570, COSV100957975, COSV66329081; called by muse, mutect2, varscan2
- CRB1 | c.1792C>T p.P598S | Missense Mutation (SNP) | VAF 21/120 reads (18%) | SIFT tolerated (0.43); PolyPhen benign (0.292); catalogued as COSV66329083; called by muse, mutect2, varscan2
- CREB3L4 | c.649G>A p.V217I | Missense Mutation (SNP) | VAF 91/125 reads (73%) | SIFT tolerated (0.26); PolyPhen benign (0.044); catalogued as COSV55131675; called by muse, mutect2, varscan2
- CRISP3 | c.457G>A p.D153N (on ENST00000371159 / NM_001368123.1; = p.D135N on NM_006061.4) | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.83); PolyPhen benign (0.061); catalogued as rs868076293, COSV53819126, COSV53819602; called by muse, mutect2, varscan2
- CRISPLD2 | c.1451C>T p.P484L | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.197); catalogued as rs199899739, COSV52277766; called by muse, mutect2, varscan2
- CRYGA | c.181G>A p.G61S | Missense Mutation (SNP) | VAF 33/79 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58015929; called by muse, mutect2, varscan2
- CRYGA | c.37C>T p.Q13* | Nonsense Mutation (SNP) | VAF 35/116 reads (30%) | catalogued as COSV58015934; called by muse, mutect2, varscan2
- CSMD1 | c.10382G>A p.G3461E (on ENST00000520002; = p.G3460E on NM_033225.6) | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1236928062, COSV59284695, COSV59316629; called by muse, mutect2, varscan2
- CSMD1 | c.7394G>A p.R2465Q (on ENST00000520002; = p.R2464Q on NM_033225.6) | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.357); catalogued as rs552956828, COSV59297016; called by muse, mutect2, varscan2
- CSMD1 | c.3509C>T p.P1170L (on ENST00000520002; = p.P1169L on NM_033225.6) | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1357340408, COSV100151348; called by muse, varscan2
- CSMD1 | c.640G>A p.G214R | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs544220269, COSV68180516, COSV68220241; called by muse, mutect2
- CSMD3 | c.1342G>A p.V448M | Missense Mutation (SNP) | VAF 48/143 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV52130346; called by muse, mutect2, varscan2
- CST1 | c.121G>A p.D41N | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs750450795, COSV59054781; called by muse, mutect2, varscan2
- CT45A10 | c.397G>A p.E133K | Missense Mutation (SNP) | VAF 47/64 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV65921097, COSV65921147, COSV65921162; called by muse, mutect2, varscan2
- CTNNA1 | c.94C>T p.L32F | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57071103, COSV57073350; called by muse, mutect2, varscan2
- CTNNA3 | c.1222G>A p.E408K | Missense Mutation (SNP) | VAF 31/68 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.298); catalogued as rs1387982830, COSV65562404; called by muse, mutect2, varscan2
- CTNNA3 | c.1052G>A p.G351E | Missense Mutation (SNP) | VAF 38/65 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65562416, COSV65609223; called by muse, mutect2, varscan2
- CUBN | c.1657C>T p.L553F | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.364); catalogued as rs1263298909, COSV100913146; called by muse, mutect2, varscan2
- CXCL5 | c.265G>A p.E89K | Missense Mutation (SNP) | VAF 62/93 reads (67%) | SIFT tolerated (0.32); PolyPhen benign (0.122); catalogued as COSV56018371; called by muse, mutect2, varscan2
- CXCL9 | c.358C>T p.R120C | Missense Mutation (SNP) | VAF 31/58 reads (53%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs1375851280, COSV53578486; called by muse, mutect2, varscan2
- CXCR2 | c.193G>A p.G65R | Missense Mutation (SNP) | VAF 41/147 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59280058; called by muse, mutect2, varscan2
- CXCR5 | c.301G>A p.V101I | Missense Mutation (SNP) | VAF 39/84 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.542); catalogued as COSV52682876; called by muse, mutect2, varscan2
- CYLC1 | c.1090A>C p.K364Q | Missense Mutation (SNP) | VAF 6/9 reads (67%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.929); catalogued as COSV61410818; called by muse, mutect2, varscan2
- CYP17A1 | c.790G>A p.D264N | Missense Mutation (SNP) | VAF 39/61 reads (64%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.802); catalogued as COSV64004795; called by muse, mutect2, varscan2
- CYP2C19 | c.1060G>A p.E354K | Missense Mutation (SNP) | VAF 82/112 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs747508319, COSV64907168, COSV64907400, COSV64907720; called by muse, mutect2, varscan2
- CYP3A43 | c.803G>A p.R268Q | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.325); catalogued as rs550420563, COSV55935425; called by muse, mutect2, varscan2
- CYP4F11 | c.1045G>A p.E349K | Missense Mutation (SNP) | VAF 33/74 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.35); catalogued as COSV56126099; called by muse, mutect2, varscan2
- CYP4F3 | c.1493C>T p.P498L | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.378); catalogued as COSV55407890; called by muse, mutect2, varscan2
- CYP4Z1 | c.117G>A p.M39I | Missense Mutation (SNP) | VAF 59/81 reads (73%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs564652252, COSV61963946; called by muse, mutect2, varscan2
- DCAF4L1 | c.184C>T p.R62W | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs760191068, COSV60786806; called by muse, mutect2, varscan2
- DCAF4L2 | c.193G>A p.D65N | Missense Mutation (SNP) | VAF 42/112 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.037); catalogued as rs867040970, COSV60477291, COSV60477750; called by muse, mutect2, varscan2
- DCC | c.158G>A p.R53Q | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT tolerated (0.07); PolyPhen benign (0.278); catalogued as rs768831554, COSV59091314; called by muse, mutect2, varscan2
- DCC | c.1981C>T p.R661* | Nonsense Mutation (SNP) | VAF 22/58 reads (38%) | catalogued as COSV59088081; called by muse, mutect2, varscan2
- DCC | c.2177C>T p.P726L | Missense Mutation (SNP) | VAF 41/113 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59091335; called by muse, mutect2, varscan2
- DCC | c.2482C>T p.P828S | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.076); catalogued as rs1453579906, COSV59091351; called by muse, mutect2, varscan2
- DCN | c.427G>A p.E143K | Missense Mutation (SNP) | VAF 30/96 reads (31%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.496); catalogued as COSV50006263; called by muse, mutect2, varscan2
- DCST2 | c.223C>T p.Q75* | Nonsense Mutation (SNP) | VAF 73/119 reads (61%) | catalogued as COSV55050706; called by muse, mutect2, varscan2
- DDI2 | c.998C>T p.S333F | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.943); catalogued as COSV60779266; called by muse, mutect2, varscan2
- DDX10 | c.376C>T p.P126S | Missense Mutation (SNP) | VAF 32/92 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV59432585; called by muse, mutect2, varscan2
- DDX60L | c.1291C>T p.Q431* | Nonsense Mutation (SNP) | VAF 10/68 reads (15%) | catalogued as COSV52710477; called by muse, mutect2, varscan2
- DEAF1 | c.611C>T p.P204L | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.81); catalogued as COSV100102212; called by muse, mutect2, varscan2
- DENND1B | c.2183C>T p.P728L | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.435); catalogued as COSV54145985; called by muse, mutect2, varscan2
- DENND3 | c.917C>T p.P306L | Missense Mutation (SNP) | VAF 42/103 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52801418; called by muse, mutect2, varscan2
- DENND5A | c.1027C>T p.P343S | Missense Mutation (SNP) | VAF 41/97 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60232315; called by muse, mutect2, varscan2
- DGAT2 | c.409C>T p.R137* | Nonsense Mutation (SNP) | VAF 37/101 reads (37%) | catalogued as rs572486802, COSV57175732; called by muse, mutect2, varscan2
- DGCR2 | c.1180C>T p.R394C | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1030949883, COSV54217244; called by muse, mutect2, varscan2
- DHX35 | c.1210C>T p.R404C | Missense Mutation (SNP) | VAF 59/152 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs149553143; called by muse, mutect2, varscan2
- DHX37 | c.2734C>T p.P912S | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.749); catalogued as rs764204216, COSV58132860; called by muse, mutect2, varscan2
- DIDO1 | c.88C>T p.R30* | Nonsense Mutation (SNP) | VAF 3/24 reads (13%) | catalogued as COSV56616435; called by muse, mutect2
- DKK2 | c.287G>A p.G96E | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.657); catalogued as COSV53395371; called by muse, mutect2, varscan2
- DLC1 | c.1859C>T p.S620F (on ENST00000276297 / NM_001348081.2; = p.S183F on NM_006094.5) | Missense Mutation (SNP) | VAF 25/135 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.982); catalogued as COSV52291251; called by muse, mutect2, varscan2
- DLGAP4 | c.373C>T p.P125S | Missense Mutation (SNP) | VAF 56/163 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.027); catalogued as COSV59415651; called by muse, mutect2, varscan2
- DMBT1 | c.454C>T p.P152S | Missense Mutation (SNP) | VAF 136/192 reads (71%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as COSV57537731; called by muse, varscan2
- DMBT1 | c.919G>A p.E307K | Missense Mutation (SNP) | VAF 35/116 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1301161488, COSV57537784; called by muse, mutect2, varscan2
- DMBT1 | c.1675G>A p.D559N | Missense Mutation (SNP) | VAF 94/151 reads (62%) | SIFT deleterious (0.01); PolyPhen benign (0.334); catalogued as COSV57537809; called by muse, mutect2, varscan2
- DMP1 | c.1453G>A p.E485K | Missense Mutation (SNP) | VAF 129/200 reads (65%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as COSV56818544; called by muse, mutect2, varscan2
- DNAAF5 | c.1108G>A p.D370N | Missense Mutation (SNP) | VAF 65/177 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.37); catalogued as rs200573334, COSV52415192; called by muse, mutect2, varscan2
- DNAH1 | c.5162C>T p.S1721F | Missense Mutation (SNP) | VAF 64/139 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs375094563, COSV70227251; called by muse, mutect2, varscan2
- DNAH10 | c.4204G>A p.E1402K (on ENST00000409039; = p.E1341K on NM_207437.3) | Missense Mutation (SNP) | VAF 28/57 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.696); catalogued as rs1000588504, COSV68989999; called by muse, mutect2, varscan2
- DNAH11 | c.9619G>A p.A3207T | Missense Mutation (SNP) | VAF 37/108 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.019); catalogued as rs750503068, COSV60945610; called by muse, mutect2, varscan2
- DNAH17 | c.4952G>A p.G1651E | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.529); catalogued as COSV67751133; called by muse, mutect2, varscan2
- DNAH3 | c.11272G>A p.E3758K | Missense Mutation (SNP) | VAF 53/56 reads (95%) | SIFT tolerated (0.09); PolyPhen benign (0.257); catalogued as rs868191973, COSV54510062; called by muse, mutect2, varscan2
- DNAH3 | c.10990G>A p.A3664T | Missense Mutation (SNP) | VAF 58/129 reads (45%) | SIFT tolerated (0.22); PolyPhen benign (0.143); catalogued as COSV54510073; called by muse, mutect2, varscan2
- DNAH5 | c.3073C>T p.P1025S | Missense Mutation (SNP) | VAF 35/60 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV54211836; called by muse, mutect2, varscan2
- DNAH5 | c.2698A>T p.K900* | Nonsense Mutation (SNP) | VAF 13/23 reads (57%) | catalogued as COSV54211845; called by muse, mutect2, varscan2
- DNAH7 | c.7228G>A p.E2410K | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56756410; called by muse, mutect2, varscan2
- DNAH7 | c.4766C>T p.S1589F | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV56756424; called by muse, mutect2, varscan2
- DNAH8 | c.8695G>A p.E2899K | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV59425499; called by muse, mutect2, varscan2
- DNAJC13 | c.5125G>A p.A1709T | Missense Mutation (SNP) | VAF 56/158 reads (35%) | SIFT tolerated (0.55); PolyPhen benign (0.188); catalogued as COSV53447452; called by muse, mutect2, varscan2
- DNASE1L3 | c.526A>G p.K176E | Missense Mutation (SNP) | VAF 14/248 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.589); catalogued as COSV59155389; called by muse, mutect2
- DNMT3B | c.394C>T p.H132Y | Missense Mutation (SNP) | VAF 19/151 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.171); catalogued as COSV52416005; called by muse, mutect2, varscan2
- DOCK3 | c.1069C>T p.H357Y | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.833); catalogued as COSV56509885; called by muse, mutect2, varscan2
- DOCK6 | c.491C>T p.S164F | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.24); PolyPhen benign (0.057); catalogued as COSV53912412; called by muse, mutect2, varscan2
- DOCK7 | c.247C>T p.P83S | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV51999519; called by muse, mutect2, varscan2
- DOCK8 | c.3442G>A p.D1148N | Missense Mutation (SNP) | VAF 50/73 reads (68%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.567); catalogued as rs767147947, COSV101210085, COSV66618709; called by muse, mutect2, varscan2
- DPPA2 | c.343-1G>A p.X115_splice | Splice Site (SNP) | VAF 76/204 reads (37%) | catalogued as COSV72117970; called by muse, mutect2, varscan2
- DPY19L3 | c.931C>T p.L311F | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); catalogued as COSV60475291; called by muse, mutect2, varscan2
- DPYD | c.2059G>A p.D687N | Missense Mutation (SNP) | VAF 97/150 reads (65%) | SIFT tolerated (0.17); PolyPhen benign (0.075); catalogued as rs998525793, COSV64593118; called by muse, mutect2, varscan2
- DRC1 | c.1108A>G p.T370A | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.56); PolyPhen benign (0.01); catalogued as COSV56529837; called by muse, mutect2, varscan2
- DRD2 | c.715C>T p.P239S | Missense Mutation (SNP) | VAF 62/164 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.01); catalogued as COSV60755876; called by muse, mutect2, varscan2
- DRP2 | c.963G>A p.W321* | Nonsense Mutation (SNP) | VAF 69/84 reads (82%) | catalogued as rs1481789166, COSV65809606; called by muse, mutect2, varscan2
- DSC2 | c.438A>T p.E146D | Missense Mutation (SNP) | VAF 27/54 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51862322; called by muse, mutect2, varscan2
- DSCAM | c.2464G>A p.E822K | Missense Mutation (SNP) | VAF 46/112 reads (41%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.74); catalogued as COSV68023112; called by muse, mutect2, varscan2
- DSCAM | c.1438G>A p.G480R | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); catalogued as COSV68023120; called by muse, varscan2
- DSCAML1 | c.5614G>A p.A1872T (on ENST00000321322; = p.A1812T on NM_020693.4) | Missense Mutation (SNP) | VAF 65/187 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58385135; called by muse, mutect2, varscan2
- DSCAML1 | c.2341G>A p.V781I (on ENST00000321322; = p.V721I on NM_020693.4) | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.805); catalogued as COSV58385153; called by muse, mutect2, varscan2
- DSCAML1 | c.1274G>A p.G425E (on ENST00000321322; = p.G365E on NM_020693.4) | Missense Mutation (SNP) | VAF 67/170 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV100356613; called by muse, mutect2, varscan2
- DSCAML1 | c.1273G>A p.G425R (on ENST00000321322; = p.G365R on NM_020693.4) | Missense Mutation (SNP) | VAF 65/169 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs370224299; called by muse, mutect2, varscan2
- DSEL | c.2309G>T p.R770I | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT tolerated (0.17); PolyPhen benign (0.299); catalogued as COSV59490161; called by muse, mutect2, varscan2
- DSG1 | c.2063G>A p.G688D | Missense Mutation (SNP) | VAF 24/104 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV57134008; called by muse, mutect2, varscan2
- DSG2 | c.2713G>A p.E905K | Missense Mutation (SNP) | VAF 33/87 reads (38%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.996); catalogued as rs1156468696, COSV55197790; called by muse, mutect2, varscan2
- DSN1 | c.584C>T p.S195L | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.341); catalogued as rs1442417522, COSV65518691; called by muse, mutect2, varscan2
- DUSP22 | c.517G>A p.G173R | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.003); catalogued as rs757843915, COSV60524977, COSV60532953; called by muse, mutect2, varscan2
- DYDC2 | c.526C>T p.P176S | Missense Mutation (SNP) | VAF 63/91 reads (69%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.009); catalogued as rs1292587644, COSV55471864; called by muse, mutect2, varscan2
- DYSF | c.5674T>C p.F1892L | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.596); catalogued as COSV50279696; called by muse, mutect2, varscan2
- EDC3 | c.202C>T p.P68S | Missense Mutation (SNP) | VAF 49/92 reads (53%) | SIFT tolerated (0.25); PolyPhen benign (0.03); catalogued as rs765222222, COSV59339519; called by muse, mutect2, varscan2
- EDIL3 | c.905G>A p.R302Q | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.971); catalogued as rs765088380, COSV56885602; called by muse, mutect2, varscan2
- EDIL3 | c.649C>T p.Q217* | Nonsense Mutation (SNP) | VAF 26/86 reads (30%) | catalogued as COSV56885612; called by muse, mutect2, varscan2
- EDNRB | c.1406C>T p.S469F (on ENST00000377211 / NM_001201397.1; = p.S379F on NM_000115.5) | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV57519936; called by muse, mutect2, varscan2
- EEF1G | c.160C>T p.P54S | Missense Mutation (SNP) | VAF 57/154 reads (37%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.764); catalogued as rs11549641, COSV57744252; called by muse, mutect2, varscan2
- EEFSEC | c.340A>T p.M114L | Missense Mutation (SNP) | VAF 104/257 reads (40%) | SIFT tolerated (0.49); PolyPhen benign (0.015); catalogued as COSV54621624; called by muse, mutect2, varscan2
- EFCAB13 | c.1570C>T p.P524S | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.647); catalogued as rs371862264, COSV58946658; called by muse, mutect2, varscan2
- EFHB | c.1991C>T p.T664I | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as COSV55545847; called by muse, mutect2, varscan2
- EIF2AK1 | c.1234C>T p.P412S | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.922); catalogued as COSV52237326; called by muse, mutect2, varscan2
- EIF4G1 | c.742C>T p.P248S (on ENST00000346169 / NM_198241.3; = p.P52S on NM_004953.5) | Missense Mutation (SNP) | VAF 35/133 reads (26%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as COSV59989811; called by muse, mutect2, varscan2
- EIF4G3 | c.3547G>A p.G1183S | Missense Mutation (SNP) | VAF 35/176 reads (20%) | SIFT tolerated (0.45); PolyPhen benign (0.218); catalogued as COSV51677095; called by muse, mutect2, varscan2
- ELOA2 | c.1798G>A p.E600K | Missense Mutation (SNP) | VAF 33/96 reads (34%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); catalogued as COSV55295225; called by muse, mutect2, varscan2
- EMB | c.883G>A p.G295R | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.155); catalogued as COSV57481159; called by muse, mutect2, varscan2
- EMILIN1 | c.125G>A p.G42E | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as COSV66694402; called by muse, mutect2, varscan2
- EML5 | c.1012C>T p.P338S | Missense Mutation (SNP) | VAF 111/143 reads (78%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.902); catalogued as COSV61343110; called by muse, mutect2, varscan2
- ENAM | c.466C>T p.P156S | Missense Mutation (SNP) | VAF 28/48 reads (58%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.563); catalogued as COSV68535492; called by muse, mutect2, varscan2
- ENPEP | c.1978G>A p.D660N | Missense Mutation (SNP) | VAF 57/85 reads (67%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.985); catalogued as rs1375611130, COSV54448212; called by muse, mutect2, varscan2
- ENPEP | c.2764G>A p.E922K | Missense Mutation (SNP) | VAF 24/37 reads (65%) | SIFT tolerated (0.18); PolyPhen benign (0.063); catalogued as COSV54448217; called by muse, mutect2, varscan2
- EPB41L2 | c.1315C>T p.R439C | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100440320, COSV61353986; called by muse, mutect2, varscan2
- EPB41L4B | c.1265A>G p.H422R | Missense Mutation (SNP) | VAF 55/69 reads (80%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.636); catalogued as rs780260303, COSV65795949; called by muse, mutect2, varscan2
- EPHA7 | c.2284C>T p.R762C | Missense Mutation (SNP) | VAF 42/86 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV65179071; called by muse, mutect2, varscan2
- EPX | c.664C>T p.L222F | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.971); catalogued as COSV56595533, COSV56596236; called by muse, mutect2, varscan2
- ERC2 | c.1175G>A p.R392Q | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as rs767117758, COSV55606932; called by muse, mutect2, varscan2
- ERI1 | c.811C>T p.P271S | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT tolerated (0.16); PolyPhen benign (0.012); catalogued as rs767093702, COSV51570795; called by muse, mutect2, varscan2
- ERICH3 | c.2877G>A p.M959I | Missense Mutation (SNP) | VAF 17/137 reads (12%) | SIFT tolerated (0.62); PolyPhen benign (0.009); catalogued as rs1238522144, COSV58601970; called by muse, mutect2, varscan2
- ESAM | c.466C>T p.P156S | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV54034039; called by muse, mutect2, varscan2
- ESR1 | c.1388C>T p.S463F | Missense Mutation (SNP) | VAF 47/157 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1289170624, COSV52784784; called by muse, mutect2, varscan2
- ESRRB | c.1147C>T p.H383Y | Missense Mutation (SNP) | VAF 42/50 reads (84%) | SIFT tolerated (1); PolyPhen benign (0.216); catalogued as COSV55059611; called by muse, mutect2, varscan2
- ESYT1 | c.118G>A p.G40S | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV57271983; called by muse, mutect2, varscan2
- EXD2 | c.1397C>T p.S466F (on ENST00000312994 / NM_001193362.1; = p.S341F on NM_018199.3) | Missense Mutation (SNP) | VAF 35/36 reads (97%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57278745; called by muse, mutect2, varscan2
- EXOC3 | c.749C>T p.T250I | Missense Mutation (SNP) | VAF 57/95 reads (60%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV59266057; called by muse, mutect2, varscan2
- EYA1 | c.614C>T p.S205F | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV58159030; called by muse, mutect2, varscan2
- EYA2 | c.1258C>T p.L420F | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.993); catalogued as COSV57940149; called by muse, mutect2, varscan2
- EZR | c.224C>T p.P75L | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs11550707, COSV61453016; called by muse, mutect2, varscan2
- F8 | c.5239C>T p.P1747S | Missense Mutation (SNP) | VAF 32/42 reads (76%) | SIFT tolerated (0.62); PolyPhen benign (0.033); catalogued as COSV100811364, COSV64270692; called by muse, mutect2, varscan2
- FAAH2 | c.1490C>T p.P497L | Missense Mutation (SNP) | VAF 21/25 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs898403004, COSV66506166; called by muse, mutect2, varscan2
- FABP12 | c.182A>T p.N61I | Missense Mutation (SNP) | VAF 35/71 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as rs745611767, COSV64616690; called by muse, mutect2, varscan2
- FAM187B | c.524C>T p.A175V | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.173); catalogued as COSV61201063, COSV61201217; called by muse, mutect2, varscan2
- FAM220A | c.526C>T p.P176S | Missense Mutation (SNP) | VAF 38/83 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0.132); catalogued as COSV57625971; called by muse, mutect2, varscan2
- FAM47A | c.1441G>A p.E481K | Missense Mutation (SNP) | VAF 43/54 reads (80%) | SIFT deleterious (0.01); PolyPhen benign (0.203); catalogued as COSV60495044; called by muse, mutect2, varscan2
- FAM47A | c.1060C>T p.P354S | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV60495049, COSV60496064; called by muse, mutect2, varscan2
- FARSA | c.904C>T p.Q302* | Nonsense Mutation (SNP) | VAF 7/17 reads (41%) | catalogued as COSV58904527; called by muse, mutect2, varscan2
- FAT3 | c.2849C>T p.P950L | Missense Mutation (SNP) | VAF 41/88 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs746609537, COSV53088460; called by muse, mutect2, varscan2
- FAT3 | c.3922C>T p.P1308S | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.876); catalogued as rs1247315871, COSV53142870, COSV99968232; called by muse, mutect2, varscan2
- FAT4 | c.11332C>T p.P3778S | Missense Mutation (SNP) | VAF 57/89 reads (64%) | SIFT deleterious (0.01); PolyPhen benign (0.022); catalogued as COSV58675914; called by muse, mutect2, varscan2
- FBXL20 | c.1030C>T p.R344C | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.224); catalogued as rs1433521578, COSV52897329; called by muse, mutect2, varscan2
- FBXL7 | c.1093G>A p.D365N | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV61643063; called by muse, mutect2, varscan2
- FBXO10 | c.2131G>A p.E711K | Missense Mutation (SNP) | VAF 18/23 reads (78%) | SIFT deleterious (0.01); PolyPhen benign (0.057); catalogued as COSV52831920; called by muse, mutect2, varscan2
- FBXO30 | c.842C>A p.S281Y | Missense Mutation (SNP) | VAF 19/170 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.049); catalogued as COSV52790527; called by muse, mutect2, varscan2
- FBXO43 | c.1322C>T p.P441L | Missense Mutation (SNP) | VAF 48/130 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV71053570; called by muse, mutect2, varscan2
- FCGBP | c.7823C>T p.S2608L | Missense Mutation (SNP) | VAF 29/198 reads (15%) | SIFT tolerated (0.32); PolyPhen benign (0.026); catalogued as rs1477485870; called by muse, mutect2, varscan2
- FCRL1 | c.1174G>A p.E392K | Missense Mutation (SNP) | VAF 45/68 reads (66%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as rs1331131199, COSV63824339, COSV63826577, COSV63826967; called by muse, mutect2, varscan2
- FDXACB1 | c.1385C>T p.T462I | Missense Mutation (SNP) | VAF 29/58 reads (50%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as rs574668776, COSV99500101; called by muse, mutect2, varscan2
- FDXACB1 | c.1384A>G p.T462A | Missense Mutation (SNP) | VAF 29/60 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99500106; called by muse, mutect2, varscan2
- FER1L6 | c.1247C>T p.S416F | Missense Mutation (SNP) | VAF 54/130 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as COSV67548784; called by muse, mutect2, varscan2
- FER1L6 | c.4135C>T p.P1379S | Missense Mutation (SNP) | VAF 72/181 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67548786; called by muse, mutect2, varscan2
- FER1L6 | c.5375C>T p.P1792L | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101206088; called by muse, mutect2, varscan2
- FFAR3 | c.109G>T p.V37L | Missense Mutation (SNP) | VAF 51/248 reads (21%) | SIFT tolerated (0.36); PolyPhen benign (0.346); catalogued as COSV59908833; called by muse, mutect2, varscan2
- FFAR4 | c.575C>T p.S192L | Missense Mutation (SNP) | VAF 26/45 reads (58%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs370316092; called by muse, mutect2, varscan2
- FGF18 | c.607C>T p.P203S | Missense Mutation (SNP) | VAF 50/102 reads (49%) | SIFT tolerated (0.15); PolyPhen benign (0.088); catalogued as rs375757183; called by muse, mutect2, varscan2
- FGF5 | c.796C>T p.R266C | Missense Mutation (SNP) | VAF 39/61 reads (64%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs137903755; called by muse, mutect2, varscan2
- FHDC1 | c.2779C>T p.P927S | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV52598548; called by muse, mutect2, varscan2
- FHDC1 | c.3028C>T p.P1010S | Missense Mutation (SNP) | VAF 57/104 reads (55%) | SIFT tolerated (0.62); PolyPhen benign (0.037); catalogued as rs1035536016, COSV52598497; called by muse, mutect2, varscan2
- FLG | c.5659G>A p.E1887K | Missense Mutation (SNP) | VAF 375/582 reads (64%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.982); catalogued as COSV64238641; called by muse, mutect2, varscan2
- FLG | c.3128G>A p.S1043N | Missense Mutation (SNP) | VAF 146/912 reads (16%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.807); catalogued as rs1300989520, COSV64238644; called by muse, mutect2, varscan2
- FLG2 | c.3289G>A p.G1097R | Missense Mutation (SNP) | VAF 109/535 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.171); catalogued as COSV66167288; called by muse, mutect2, varscan2
- FLNA | c.2527dup p.A843Gfs*12 | Frame Shift Ins (INS) | VAF 62/116 reads (53%) | catalogued as rs782312089; called by pindel, varscan2
- FOXJ3 | c.1091C>T p.S364L | Missense Mutation (SNP) | VAF 25/246 reads (10%) | SIFT tolerated (0.3); PolyPhen benign (0.039); catalogued as rs774386854, COSV100691513, COSV62360072; called by muse, mutect2
- FOXM1 | c.1218G>A p.M406I | Missense Mutation (SNP) | VAF 83/152 reads (55%) | SIFT tolerated (0.19); PolyPhen benign (0.035); catalogued as rs750630091, COSV61205509; called by muse, mutect2, varscan2
- FREM1 | c.4690C>T p.Q1564* | Nonsense Mutation (SNP) | VAF 64/85 reads (75%) | catalogued as COSV66519732; called by muse, mutect2, varscan2
- FREM2 | c.6238C>T p.R2080C | Missense Mutation (SNP) | VAF 51/166 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.761); catalogued as rs367867609, COSV99747088; called by muse, mutect2, varscan2
- FRMD7 | c.647G>A p.G216E | Missense Mutation (SNP) | VAF 21/25 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1322869713, COSV53745213; called by muse, mutect2, varscan2
- FRMPD2 | c.3826G>A p.E1276K | Missense Mutation (SNP) | VAF 22/34 reads (65%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV100564029; called by mutect2, varscan2
- FRMPD2 | c.275G>A p.G92E | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT tolerated (0.16); PolyPhen benign (0.036); catalogued as rs1248557124, COSV59716248; called by muse, mutect2, varscan2
- FRMPD3 | c.4255C>T p.P1419S | Missense Mutation (SNP) | VAF 49/61 reads (80%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV52188092; called by muse, mutect2, varscan2
- FSTL5 | c.2311C>T p.L771F | Missense Mutation (SNP) | VAF 59/84 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60185517; called by muse, mutect2, varscan2
- FSTL5 | c.1157C>T p.S386F | Missense Mutation (SNP) | VAF 46/71 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60185521; called by muse, mutect2, varscan2
- FSTL5 | c.59G>A p.G20E | Missense Mutation (SNP) | VAF 46/80 reads (58%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.005); catalogued as COSV60185527; called by muse, mutect2, varscan2
- FURIN | c.826C>T p.R276C | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs757486890, COSV51575420; called by muse, mutect2, varscan2
- FUT9 | c.182T>G p.F61C | Missense Mutation (SNP) | VAF 51/96 reads (53%) | SIFT tolerated (0.14); PolyPhen benign (0.087); catalogued as COSV56143801, COSV56145776; called by muse, mutect2, varscan2
- FYB1 | c.1643G>A p.G548E | Missense Mutation (SNP) | VAF 31/81 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60942234; called by muse, mutect2, varscan2
- FYB1 | c.1199C>T p.P400L | Missense Mutation (SNP) | VAF 45/175 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs746531540, COSV60941976; called by muse, mutect2, varscan2
- GABRA6 | c.202G>A p.G68R | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs868523981, COSV50878091, COSV50878426; called by muse, mutect2, varscan2
- GALNT11 | c.223A>C p.K75Q | Missense Mutation (SNP) | VAF 37/91 reads (41%) | SIFT tolerated (0.16); PolyPhen benign (0.013); catalogued as COSV57424999; called by muse, mutect2, varscan2
- GALNT9 | c.1316G>A p.R439K (on ENST00000328957 / NM_001122636.2; = p.R73K on NM_021808.3) | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.76); PolyPhen benign (0.003); catalogued as COSV61096924; called by muse, mutect2, varscan2
- GALNTL6 | c.1240G>A p.D414N | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs1342803335, COSV72490023; called by muse, mutect2, varscan2
- GBA | c.850C>T p.P284S | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT tolerated (0.37); PolyPhen benign (0.22); catalogued as CM134809, COSV59169250; called by muse, mutect2, varscan2
- GBP7 | c.1545G>A p.M515I | Missense Mutation (SNP) | VAF 69/137 reads (50%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV54008648; called by muse, mutect2, varscan2
- GCDH | c.1091C>T p.P364L | Missense Mutation (SNP) | VAF 95/295 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as COSV53366007; called by muse, mutect2, varscan2
- GHR | c.425C>T p.S142F | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs865987331, COSV50106764; called by muse, mutect2, varscan2
- GIMAP1 | c.811C>T p.P271S | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.4); PolyPhen benign (0.015); catalogued as COSV56187458; called by muse, mutect2, varscan2
- GIMAP5 | c.698C>T p.T233I | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV57529780; called by muse, mutect2, varscan2
- GJA10 | c.218C>T p.S73F | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65354908, COSV65356066; called by muse, mutect2, varscan2
- GJB5 | c.325C>T p.H109Y | Missense Mutation (SNP) | VAF 97/146 reads (66%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV58355685; called by muse, mutect2, varscan2
- GLI2 | c.1972C>T p.P658S (on ENST00000361492 / NM_001374353.1; = p.P675S on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT tolerated (0.66); PolyPhen benign (0.055); catalogued as COSV100083799; called by muse, mutect2, varscan2
- GLI2 | c.1973C>T p.P658L (on ENST00000361492 / NM_001374353.1; = p.P675L on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.602); catalogued as COSV100083802; called by muse, mutect2, varscan2
- GLP1R | c.1113G>A p.M371I | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV100952627, COSV64714565; called by muse, mutect2, varscan2
- GLYATL1 | c.226C>T p.R76C (on ENST00000317391 / NM_001354699.1; = p.R107C on NM_080661.4) | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs151204927, COSV55607318; called by muse, mutect2, varscan2
- GLYATL2 | c.482G>A p.G161E | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs868520769, COSV54849352; called by muse, mutect2
- GNAS | c.781T>A p.S261T | Missense Mutation (SNP) | VAF 21/37 reads (57%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.05); catalogued as COSV58330281; called by muse, mutect2, varscan2
- GNAT1 | c.940G>A p.E314K | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs779330892, COSV51696665, COSV51696866; called by muse, mutect2, varscan2
- GNG4 | c.92G>A p.R31K | Missense Mutation (SNP) | VAF 106/152 reads (70%) | SIFT deleterious (0.01); PolyPhen benign (0.334); catalogued as COSV63999039; called by muse, mutect2, varscan2
- GOLGA6B | c.1861G>A p.G621S | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.78); PolyPhen benign (0.087); catalogued as rs918306187, COSV101406931; called by mutect2, varscan2
- GON4L | c.3311C>T p.S1104F | Missense Mutation (SNP) | VAF 88/135 reads (65%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.909); catalogued as rs138268831; called by muse, mutect2, varscan2
- GPC4 | c.340G>A p.E114K | Missense Mutation (SNP) | VAF 61/130 reads (47%) | SIFT tolerated (0.37); PolyPhen benign (0.074); catalogued as COSV63697297; called by muse, mutect2, varscan2
- GPHN | c.1159C>T p.R387C (on ENST00000315266 / NM_001377519.1; = p.R420C on NM_020806.5) | Missense Mutation (SNP) | VAF 23/30 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59473880; called by muse, mutect2, varscan2
- GPX5 | c.376G>A p.G126R | Missense Mutation (SNP) | VAF 54/149 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.153); catalogued as COSV69079203; called by muse, mutect2, varscan2
- GRID2 | c.1205G>A p.G402E | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs999075268, COSV56184366; called by muse, mutect2, varscan2
- GRIK2 | c.91G>A p.G31R | Missense Mutation (SNP) | VAF 10/113 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.066); catalogued as COSV100027775; called by muse, mutect2
- GRIK2 | c.92G>A p.G31E | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.044); catalogued as COSV100027779; called by muse, mutect2
- GRIK3 | c.2624G>A p.R875Q | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT tolerated (0.29); PolyPhen benign (0.173); catalogued as rs765733567, COSV66136946, COSV66145394; called by muse, mutect2, varscan2
- GRIP1 | c.776C>T p.P259L | Missense Mutation (SNP) | VAF 35/61 reads (57%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.721); catalogued as COSV54018455; called by muse, mutect2, varscan2
- GRM2 | c.8C>T p.S3L | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0); catalogued as COSV56583411; called by muse, mutect2, varscan2
- GRM5 | c.1579G>A p.E527K | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as COSV59596111, COSV59611371; called by muse, mutect2, varscan2
- GRM8 | c.2081C>A p.S694Y | Missense Mutation (SNP) | VAF 40/67 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.627); catalogued as COSV58811502; called by muse, mutect2, varscan2
- GRPR | c.1081C>T p.L361F | Missense Mutation (SNP) | VAF 62/90 reads (69%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs769113444, COSV100977683; called by muse, mutect2, varscan2
- GRXCR1 | c.41G>A p.R14Q | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.011); catalogued as COSV67669920; called by muse, mutect2, varscan2
- GSTA1 | c.650G>A p.R217K | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58014770; called by muse, mutect2, varscan2
- GSTA2 | c.554A>G p.K185R | Missense Mutation (SNP) | VAF 40/100 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.432); catalogued as COSV72414739; called by muse, mutect2, varscan2
- GUCY2F | c.2539G>A p.E847K | Missense Mutation (SNP) | VAF 59/70 reads (84%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.573); catalogued as COSV54299769, COSV54305022; called by muse, mutect2, varscan2
- GZF1 | c.73C>T p.R25C | Missense Mutation (SNP) | VAF 38/66 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs140549788; called by muse, mutect2, varscan2
- H1-7 | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as rs1398389521, COSV58601839; called by muse, mutect2, varscan2
- H3C2 | c.229C>T p.Q77* | Nonsense Mutation (SNP) | VAF 78/159 reads (49%) | catalogued as COSV52518118; called by muse, mutect2, varscan2
- HAL | c.1126C>T p.H376Y | Missense Mutation (SNP) | VAF 24/45 reads (53%) | SIFT deleterious (0.05); PolyPhen benign (0.009); catalogued as COSV54116915; called by muse, mutect2, varscan2
- HAO1 | c.134C>T p.S45F | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.496); catalogued as rs1281967601, COSV101113263; called by muse, mutect2, varscan2
- HAO2 | c.41G>A p.R14Q | Missense Mutation (SNP) | VAF 145/192 reads (76%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as rs760870079, COSV58038381; called by muse, mutect2, varscan2
- HAO2 | c.646C>T p.R216* | Nonsense Mutation (SNP) | VAF 22/90 reads (24%) | catalogued as rs587640182, COSV58038394; called by muse, mutect2, varscan2
- HCK | c.345G>A p.W115* | Nonsense Mutation (SNP) | VAF 13/186 reads (7%) | catalogued as COSV52941157; called by muse, mutect2
- HCLS1 | c.1241-1G>A p.X414_splice | Splice Site (SNP) | VAF 18/54 reads (33%) | catalogued as rs763119132, COSV57522591; called by muse, mutect2, varscan2
- HCRTR2 | c.403-1G>A p.X135_splice | Splice Site (SNP) | VAF 32/49 reads (65%) | catalogued as COSV63794512; called by muse, mutect2, varscan2
- HDAC9 | c.647G>A p.R216Q | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV67769639; called by muse, mutect2, varscan2
- HDC | c.1372G>A p.D458N | Missense Mutation (SNP) | VAF 29/57 reads (51%) | SIFT tolerated (0.1); PolyPhen benign (0.127); catalogued as rs267604244, COSV51068734; called by muse, mutect2, varscan2
- HECW1 | c.178G>A p.G60S | Missense Mutation (SNP) | VAF 31/84 reads (37%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0.01); catalogued as COSV67825349; called by muse, mutect2, varscan2
- HECW1 | c.391C>T p.R131C | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs748846572, COSV67825353; called by muse, mutect2, varscan2
- HEPHL1 | c.1090G>A p.D364N | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV59890295; called by muse, mutect2, varscan2
- HHIP | c.257G>A p.G86E | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.062); catalogued as COSV56837792; called by muse, mutect2, varscan2
- HIC2 | c.434C>T p.P145L | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.357); catalogued as COSV68041816; called by muse, mutect2, varscan2
- HIC2 | c.859C>T p.P287S | Missense Mutation (SNP) | VAF 50/124 reads (40%) | SIFT tolerated (0.73); PolyPhen benign (0.003); catalogued as rs566029601, COSV68041819; called by muse, mutect2, varscan2
- HIVEP3 | c.4909C>T p.P1637S | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV56011349; called by muse, mutect2, varscan2
- HMGCLL1 | c.560C>T p.S187F | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs780798314, COSV51441774; called by muse, mutect2, varscan2
- HNRNPM | c.1648C>T p.R550C | Missense Mutation (SNP) | VAF 66/153 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs775936036, COSV55312607; called by muse, mutect2, varscan2
- HOXB3 | c.1217C>T p.T406I | Missense Mutation (SNP) | VAF 57/137 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57486161; called by muse, mutect2, varscan2
- HRC | c.2046C>A p.F682L | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.1); catalogued as COSV53255602; called by muse, mutect2, varscan2
- HRG | c.928C>T p.P310S | Missense Mutation (SNP) | VAF 37/81 reads (46%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV51644530; called by muse, mutect2, varscan2
- HRNR | c.5146G>A p.G1716S | Missense Mutation (SNP) | VAF 80/780 reads (10%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as rs756291117; called by muse, mutect2, varscan2
- HS6ST3 | c.953G>A p.S318N | Missense Mutation (SNP) | VAF 49/91 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); catalogued as COSV65004576; called by muse, mutect2, varscan2
- HSD17B13 | c.304C>T p.R102C | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.849); catalogued as rs778806212, COSV56345570; called by muse, mutect2, varscan2
- HSD3B1 | c.406G>A p.E136K | Missense Mutation (SNP) | VAF 194/273 reads (71%) | SIFT tolerated (0.09); PolyPhen benign (0.023); catalogued as COSV52489806; called by muse, mutect2, varscan2
- HSD3B7 | c.359G>A p.G120E | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as COSV52679939; called by muse, mutect2, varscan2
- HSPG2 | c.2258C>T p.P753L | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101020916; called by muse, mutect2, varscan2
- HSPG2 | c.2257C>T p.P753S | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); catalogued as rs1347601746, COSV101020917; called by muse, mutect2, varscan2
- HTR2C | c.446C>T p.S149L | Missense Mutation (SNP) | VAF 51/64 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1556468166, COSV52204453; called by muse, mutect2, varscan2
- HTR2C | c.562C>T p.P188S | Missense Mutation (SNP) | VAF 31/46 reads (67%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.889); catalogued as rs868956836, COSV52204464; called by muse, mutect2, varscan2
- HTR3C | c.977C>T p.T326I | Missense Mutation (SNP) | VAF 42/112 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV59174581; called by muse, mutect2, varscan2
- HTRA2 | c.269C>T p.T90I | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV51206475; called by muse, mutect2, varscan2
- HYAL3 | c.673C>T p.L225F | Missense Mutation (SNP) | VAF 38/100 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.246); catalogued as COSV56497045; called by muse, mutect2, varscan2
- HYDIN | c.13239G>A p.M4413I | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV66637944; called by muse, mutect2, varscan2
- HYDIN | c.12337G>A p.E4113K | Missense Mutation (SNP) | VAF 33/105 reads (31%) | SIFT tolerated (0.52); PolyPhen benign (0.033); catalogued as COSV66637950; called by muse, mutect2, varscan2
- HYDIN | c.2662G>A p.E888K | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.19); PolyPhen benign (0.011); catalogued as rs751437046, COSV100376363, COSV100378917; called by mutect2, varscan2
- IDH1 | c.520+2T>C p.X174_splice | Splice Site (SNP) | VAF 24/64 reads (38%) | catalogued as COSV61619029; called by muse, mutect2, varscan2
- IGDCC4 | c.2740G>A p.E914K | Missense Mutation (SNP) | VAF 25/109 reads (23%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.792); catalogued as COSV61535927; called by muse, mutect2, varscan2
- IGSF1 | c.3301G>A p.E1101K | Missense Mutation (SNP) | VAF 139/169 reads (82%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV63836636; called by muse, mutect2, varscan2
- IGSF21 | c.1202G>A p.R401Q | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.988); catalogued as rs763564126, COSV52127465, COSV99244443; called by muse, mutect2, varscan2
- IL1F10 | c.233C>T p.S78F | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.133); catalogued as rs1366367422, COSV61750410; called by muse, varscan2
- IL1RAPL1 | c.2091A>G p.*697Wext*55 | Nonstop Mutation (SNP) | VAF 16/18 reads (89%) | catalogued as COSV56245964; called by muse, mutect2, varscan2
- IL1RL2 | c.808G>A p.V270M | Missense Mutation (SNP) | VAF 36/90 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV51813894; called by muse, mutect2, varscan2
- IL7R | c.611A>T p.K204I | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV57406814, COSV57412749; called by muse, mutect2, varscan2
- INCA1 | c.53G>A p.R18K | Missense Mutation (SNP) | VAF 26/37 reads (70%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as rs1457035020, COSV61788204; called by muse, mutect2, varscan2
- INHBE | c.443G>A p.R148K | Missense Mutation (SNP) | VAF 43/187 reads (23%) | SIFT tolerated (0.88); PolyPhen benign (0.03); catalogued as COSV56987643; called by muse, mutect2, varscan2
- INPP5D | c.655G>A p.E219K (on ENST00000445964 / NM_001017915.3; = p.E218K on NM_005541.5) | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated (0.46); PolyPhen benign (0.058); catalogued as COSV64036099; called by muse, mutect2, varscan2
- INTS1 | c.1766C>T p.A589V | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.844); catalogued as rs866540709, COSV67176750; called by muse, mutect2, varscan2
- INTS5 | c.1000C>T p.L334F | Missense Mutation (SNP) | VAF 35/188 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.373); catalogued as rs1408204357, COSV100399736, COSV100399747; called by muse, mutect2, varscan2
- IRS4 | c.1517G>A p.G506D | Missense Mutation (SNP) | VAF 33/87 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); catalogued as COSV64533049; called by muse, mutect2, varscan2
- ISLR | c.259C>T p.R87C | Missense Mutation (SNP) | VAF 28/52 reads (54%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.876); catalogued as rs1233443000, COSV51433274; called by muse, mutect2, varscan2
- ITGA7 | c.505G>A p.D169N | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT tolerated (0.15); PolyPhen benign (0.132); catalogued as rs1254098171, COSV57693062; called by muse, mutect2, varscan2
- ITGAD | c.1585G>A p.D529N | Missense Mutation (SNP) | VAF 91/243 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV66757169; called by muse, mutect2, varscan2
- ITGAM | c.940C>T p.Q314* | Nonsense Mutation (SNP) | VAF 14/48 reads (29%) | catalogued as COSV54935105; called by muse, mutect2, varscan2
- ITGB5 | c.472C>T p.R158W | Missense Mutation (SNP) | VAF 56/116 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs757804776, COSV99950927; called by muse, mutect2, varscan2
- ITGBL1 | c.793C>T p.H265Y | Missense Mutation (SNP) | VAF 106/204 reads (52%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.869); catalogued as COSV66006401; called by muse, mutect2, varscan2
- ITIH1 | c.2710G>A p.D904N | Missense Mutation (SNP) | VAF 30/63 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV56253279; called by muse, mutect2, varscan2
- ITIH6 | c.1543G>A p.E515K | Missense Mutation (SNP) | VAF 18/24 reads (75%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as COSV54487493; called by muse, mutect2, varscan2
- ITPR1 | c.7853G>A p.R2618K (on ENST00000354582; = p.R2563K on NM_002222.7) | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV56973725; called by muse, mutect2, varscan2
- ITPRID1 | c.23G>A p.G8E | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.439); catalogued as COSV60071086; called by muse, mutect2, varscan2
- ITSN2 | c.1754C>T p.S585L | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT tolerated (0.6); PolyPhen probably damaging (0.966); catalogued as COSV61944815; called by muse, mutect2, varscan2
- JAK3 | c.1307G>A p.G436E | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.052); catalogued as COSV71685820; called by muse, mutect2, varscan2
- JAKMIP2 | c.545G>A p.G182E | Missense Mutation (SNP) | VAF 69/169 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54599827; called by muse, mutect2, varscan2
- JARID2 | c.56A>T p.D19V | Missense Mutation (SNP) | VAF 29/194 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.121); catalogued as COSV59186902; called by muse, mutect2, varscan2
- JMY | c.2659G>A p.V887M | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.839); catalogued as COSV68659869; called by muse, mutect2, varscan2
- KBTBD11 | c.1340C>T p.A447V | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV57223238; called by muse, mutect2
- KBTBD7 | c.248C>T p.S83F | Missense Mutation (SNP) | VAF 42/112 reads (38%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as COSV65266171; called by muse, mutect2, varscan2
- KCNQ1 | c.1451G>A p.S484N | Missense Mutation (SNP) | VAF 74/167 reads (44%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.978); catalogued as COSV50102393; called by muse, mutect2, varscan2
- KCNQ5 | c.2726G>A p.R909Q | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.203); catalogued as rs184951305, COSV100573017; called by muse, mutect2, varscan2
- KCNT2 | c.1021G>A p.D341N | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.888); catalogued as COSV54069552; called by muse, mutect2, varscan2
- KCNT2 | c.68G>A p.G23E | Missense Mutation (SNP) | VAF 21/133 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.976); catalogued as COSV54064698, COSV54069570; called by muse, mutect2, varscan2
- KCNV1 | c.757T>C p.F253L | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV52085155; called by muse, mutect2, varscan2
- KCTD3 | c.376C>T p.H126Y | Missense Mutation (SNP) | VAF 14/124 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.028); catalogued as COSV52065010; called by muse, mutect2, varscan2
- KEL | c.738C>T p.I246= | Splice Region (SNP) | VAF 27/65 reads (42%) | catalogued as COSV62333953; called by muse, mutect2, varscan2
- KEL | c.436G>A p.E146K | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.401); catalogued as rs762799244, CD151479, COSV62333883; called by muse, mutect2, varscan2
- KIAA1217 | c.1825G>A p.D609N | Missense Mutation (SNP) | VAF 37/56 reads (66%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.713); catalogued as rs1272657340, COSV56813851; called by muse, mutect2, varscan2
- KIAA1217 | c.5152C>T p.P1718S | Missense Mutation (SNP) | VAF 23/35 reads (66%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV56813868; called by muse, mutect2, varscan2
- KIAA1549L | c.4360T>C p.C1454R (on ENST00000321505; = p.C1751R on NM_012194.3) | Missense Mutation (SNP) | VAF 35/78 reads (45%) | SIFT tolerated (0.48); PolyPhen benign (0.021); catalogued as COSV58584016; called by muse, mutect2, varscan2
- KIAA1755 | c.1267C>T p.P423S | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.133); catalogued as rs1320612596, COSV54074667; called by muse, mutect2, varscan2
- KIF13B | c.3707A>G p.Q1236R | Missense Mutation (SNP) | VAF 45/106 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.352); catalogued as COSV72954293; called by muse, mutect2, varscan2
- KIF5A | c.2512G>A p.E838K | Missense Mutation (SNP) | VAF 32/77 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.489); catalogued as COSV54052551; called by muse, mutect2, varscan2
- KIR2DL4 | c.418C>T p.H140Y (on ENST00000396284; = p.H101Y on NM_001080770.2) | Missense Mutation (SNP) | VAF 58/120 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV60881204; called by muse, varscan2
- KLHL13 | c.1460G>A p.G487E | Missense Mutation (SNP) | VAF 34/43 reads (79%) | SIFT deleterious (0.04); PolyPhen benign (0.036); catalogued as COSV53245800; called by muse, mutect2, varscan2
- KLHL20 | c.117A>T p.Q39H | Missense Mutation (SNP) | VAF 89/120 reads (74%) | SIFT tolerated (0.11); PolyPhen benign (0.243); catalogued as COSV52940833; called by muse, mutect2, varscan2
- KLHL38 | c.899G>A p.R300K | Missense Mutation (SNP) | VAF 23/105 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as COSV100384500, COSV100384724; called by muse, mutect2, varscan2
- KLHL38 | c.898A>G p.R300G | Missense Mutation (SNP) | VAF 24/105 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.334); catalogued as rs1289512883, COSV100384501, COSV100384726; called by muse, mutect2, varscan2
- KLHL41 | c.37C>T p.L13F | Missense Mutation (SNP) | VAF 43/98 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV52929699; called by muse, mutect2, varscan2
- KLHL5 | c.1093G>A p.E365K | Missense Mutation (SNP) | VAF 63/95 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs760181703, COSV54672695, COSV54679620; called by muse, mutect2, varscan2
- KLK2 | c.481G>A p.E161K | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.57); PolyPhen benign (0.006); catalogued as rs371591640; called by muse, mutect2, varscan2
- KLK4 | c.305C>T p.S102F | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV60675929; called by muse, mutect2, varscan2
- KLRK1 | c.191G>A p.G64E | Missense Mutation (SNP) | VAF 17/27 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs753001440, COSV53698178; called by muse, mutect2, varscan2
- KPNA5 | c.1612C>T p.Q538* | Nonsense Mutation (SNP) | VAF 18/69 reads (26%) | catalogued as COSV62651634; called by muse, mutect2, varscan2
- KRT1 | c.1486G>A p.E496K | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV52865539; called by muse, mutect2, varscan2
- KRT13 | c.350C>T p.S117F | Missense Mutation (SNP) | VAF 73/171 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs267604871, COSV55839363; called by muse, mutect2, varscan2
- KRT18 | c.791G>A p.R264Q | Missense Mutation (SNP) | VAF 21/36 reads (58%) | SIFT tolerated (0.76); PolyPhen benign (0.037); catalogued as rs762129501, COSV66315972; called by muse, mutect2, varscan2
- KRT19 | c.345G>A p.W115* | Nonsense Mutation (SNP) | VAF 44/119 reads (37%) | catalogued as COSV64238116; called by muse, mutect2, varscan2
- KRT28 | c.200G>A p.G67E | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.616); catalogued as COSV60684042; called by muse, mutect2, varscan2
- KRT3 | c.505G>A p.G169R | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.655); catalogued as COSV58814939; called by muse, mutect2, varscan2
- KRT34 | c.1034G>A p.S345N | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.497); catalogued as rs1402044843, COSV67449466; called by muse, mutect2, varscan2
- KRT34 | c.23C>T p.P8L | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.012); catalogued as rs750486261, COSV101222693; called by muse, mutect2, varscan2
- KRT5 | c.1646G>A p.G549E | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.466); catalogued as COSV52859492; called by muse, mutect2, varscan2
- KRT6C | c.1161G>A p.M387I | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT tolerated (0.05); PolyPhen benign (0.159); catalogued as rs747710925, COSV52876893; called by muse, mutect2, varscan2
- KRT86 | c.984G>A p.M328I | Missense Mutation (SNP) | VAF 29/103 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs752211932, COSV53291952; called by muse, mutect2, varscan2
- KRTAP6-1 | c.185G>A p.G62E | Missense Mutation (SNP) | VAF 90/229 reads (39%) | PolyPhen possibly damaging (0.844); catalogued as rs144374144, COSV58169017; called by muse, mutect2, varscan2
- L3MBTL1 | c.529G>A p.D177N (on ENST00000418998 / NM_001377303.1; = p.D87N on NM_015478.7) | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as COSV64230912; called by muse, mutect2, varscan2
- LACRT | c.338G>A p.G113E | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.948); catalogued as COSV57688048; called by muse, mutect2, varscan2
- LAMA1 | c.1780G>A p.D594N | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.157); catalogued as rs143022454; called by muse, mutect2, varscan2
- LAMA2 | c.185G>A p.G62E | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.212); catalogued as rs769893713, COSV70342341; called by muse, mutect2, varscan2
- LAMA2 | c.639G>A p.E213= | Splice Region (SNP) | VAF 18/62 reads (29%) | catalogued as COSV70342345; called by muse, mutect2, varscan2
- LAMA2 | c.6041G>A p.R2014K | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV70342362, COSV70350430; called by muse, mutect2, varscan2
- LAMA3 | c.7636G>A p.D2546N (on ENST00000313654 / NM_198129.4; = p.D937N on NM_000227.6) | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT tolerated (0.36); PolyPhen benign (0.073); catalogued as COSV52531804; called by muse, mutect2, varscan2
- LAMP5 | c.127C>T p.P43S | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT tolerated (0.12); PolyPhen probably damaging (1); catalogued as rs779013828, COSV55715490; called by muse, mutect2, varscan2
- LARS1 | c.864C>G p.F288L (on ENST00000394434 / NM_020117.11; = p.F261L on NM_016460.3) | Missense Mutation (SNP) | VAF 16/26 reads (62%) | SIFT deleterious (0); PolyPhen benign (0.117); catalogued as COSV50973057, COSV50973096; called by muse, mutect2, varscan2
- LCN1 | c.436G>A p.E146K | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV55017577; called by muse, mutect2, varscan2
- LCT | c.2191G>A p.G731R | Missense Mutation (SNP) | VAF 35/100 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51545785; called by muse, mutect2, varscan2
- LELP1 | c.196C>T p.P66S | Missense Mutation (SNP) | VAF 75/111 reads (68%) | SIFT tolerated, low confidence (0.28); PolyPhen possibly damaging (0.858); catalogued as rs1274556671, COSV64202354; called by muse, mutect2, varscan2
- LEXM | c.1121G>A p.R374Q | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.622); catalogued as COSV64022330; called by muse, mutect2, varscan2
- LGR6 | c.1841C>T p.S614F (on ENST00000367278 / NM_001017403.1; = p.S562F on NM_021636.3) | Missense Mutation (SNP) | VAF 35/47 reads (74%) | SIFT tolerated (0.63); PolyPhen possibly damaging (0.864); catalogued as COSV55153173; called by muse, mutect2, varscan2
- LGSN | c.1058C>T p.A353V | Missense Mutation (SNP) | VAF 40/118 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.836); catalogued as COSV65726500; called by muse, mutect2, varscan2
- LINGO3 | c.569C>T p.S190F | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV101347273; called by muse, mutect2, varscan2
- LIPH | c.1199C>T p.S400F | Missense Mutation (SNP) | VAF 37/96 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.519); catalogued as COSV56183218; called by muse, mutect2, varscan2
- LMOD1 | c.451G>A p.E151K | Missense Mutation (SNP) | VAF 24/137 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.214); catalogued as COSV66172099; called by muse, mutect2, varscan2
- LMTK3 | c.441G>A p.V147= | Splice Region (SNP) | VAF 22/62 reads (35%) | catalogued as COSV54310569; called by muse, mutect2, varscan2
- LPAR3 | c.644G>A p.R215K | Missense Mutation (SNP) | VAF 49/76 reads (64%) | SIFT tolerated (0.27); PolyPhen benign (0.063); catalogued as COSV65452602; called by muse, mutect2, varscan2
- LRBA | c.7315C>T p.R2439* | Nonsense Mutation (SNP) | VAF 45/63 reads (71%) | catalogued as COSV63951655; called by muse, mutect2, varscan2
- LRBA | c.674G>A p.W225* | Nonsense Mutation (SNP) | VAF 23/34 reads (68%) | catalogued as COSV63951658; called by muse, mutect2, varscan2
- LRIT3 | c.1093C>T p.P365S | Missense Mutation (SNP) | VAF 35/185 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.053); catalogued as COSV59983657; called by muse, mutect2, varscan2
- LRP1B | c.6151G>A p.E2051K | Missense Mutation (SNP) | VAF 18/103 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as rs867636848, COSV67198052; called by muse, mutect2, varscan2
- LRP1B | c.6113G>A p.G2038E | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.824); catalogued as rs1190814401, COSV67198055, COSV67283725; called by muse, mutect2, varscan2
- LRP2 | c.8440G>A p.E2814K | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55545475; called by muse, mutect2, varscan2
- LRP4 | c.2855C>T p.T952I | Missense Mutation (SNP) | VAF 35/88 reads (40%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.922); catalogued as COSV66134683; called by muse, mutect2, varscan2
- LRRC3B | c.169G>A p.E57K | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.56); catalogued as rs1447656470, COSV67519995; called by muse, mutect2, varscan2
- LRRC4C | c.718C>T p.Q240* | Nonsense Mutation (SNP) | VAF 34/80 reads (43%) | catalogued as COSV53420667; called by muse, mutect2, varscan2
- LRRC7 | c.2753A>T p.E918V (on ENST00000651989 / NM_001370785.2; = p.E885V on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/143 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.897); catalogued as COSV50425571; called by muse, mutect2, varscan2
- LRRC7 | c.4439G>A p.G1480E (on ENST00000651989 / NM_001370785.2; = p.G1400E on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/96 reads (18%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.941); catalogued as COSV50425725; called by muse, mutect2, varscan2
- LRRIQ3 | c.1726G>A p.E576K | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT tolerated (0.27); PolyPhen benign (0.033); catalogued as COSV63042045, COSV63042170; called by muse, mutect2, varscan2
- LRTM1 | c.326C>T p.S109L | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT tolerated (0.57); PolyPhen benign (0.077); catalogued as COSV55523265; called by muse, mutect2, varscan2
- LSP1 | c.52G>A p.G18R | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as COSV61133072; called by muse, mutect2
- LTA | c.106C>T p.P36S | Missense Mutation (SNP) | VAF 41/69 reads (59%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as COSV69304319; called by muse, mutect2, varscan2
- LTN1 | c.3613C>T p.L1205F | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs779648360, COSV63733275; called by muse, mutect2, varscan2
- LZTS3 | c.1971G>T p.K657N (on ENST00000329152; = p.K611N on NM_001282533.2) | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0.01); catalogued as COSV53904732; called by muse, varscan2
- MACF1 | c.21656C>T p.S7219F (on ENST00000372915; = p.S5264F on NM_012090.5) | Missense Mutation (SNP) | VAF 13/87 reads (15%) | catalogued as COSV57111724; called by muse, mutect2, varscan2
- MAGEA6 | c.580C>T p.Q194* | Nonsense Mutation (SNP) | VAF 75/87 reads (86%) | catalogued as COSV61448776; called by muse, mutect2, varscan2
- MAGEB16 | c.263G>A p.S88N | Missense Mutation (SNP) | VAF 8/9 reads (89%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.531); catalogued as COSV67873694; called by muse, mutect2, varscan2
- MAGEC1 | c.1600C>T p.P534S | Missense Mutation (SNP) | VAF 105/138 reads (76%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); catalogued as COSV53569756; called by muse, mutect2, varscan2
- MAGEL2 | c.3034G>A p.V1012M | Missense Mutation (SNP) | VAF 19/33 reads (58%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.003); catalogued as rs1283338365, COSV58566321; called by muse, mutect2, varscan2
- MAMDC2 | c.1304A>C p.E435A | Missense Mutation (SNP) | VAF 47/73 reads (64%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.759); catalogued as COSV65857187; called by muse, mutect2, varscan2
- MANSC1 | c.1126C>T p.Q376* | Nonsense Mutation (SNP) | VAF 16/57 reads (28%) | catalogued as COSV67110745; called by muse, mutect2, varscan2
- MAP4K1 | c.2335G>A p.D779N | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as rs761144774, COSV67709190; called by muse, mutect2, varscan2
- MAPK4 | c.1157C>T p.S386L | Missense Mutation (SNP) | VAF 30/64 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.844); catalogued as COSV68541385; called by muse, mutect2, varscan2
- MAPK6 | c.464C>T p.P155L | Missense Mutation (SNP) | VAF 32/69 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV55929183; called by muse, mutect2, varscan2
- MAPT | c.1469C>T p.P490L (on ENST00000262410 / NM_001377265.1; = p.P415L on NM_016835.4) | Missense Mutation (SNP) | VAF 136/363 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52238359; called by muse, mutect2, varscan2
- MARCHF10 | c.1997G>A p.G666E | Missense Mutation (SNP) | VAF 43/96 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV60885930; called by muse, mutect2, varscan2
- MATN4 | c.1099G>A p.G367R (on ENST00000372754; = p.G326R on NM_003833.4) | Missense Mutation (SNP) | VAF 9/57 reads (16%) | PolyPhen probably damaging (1); catalogued as rs754511732, COSV100637148, COSV61350688; called by muse, mutect2, varscan2
- MCHR2 | c.508G>A p.V170I | Missense Mutation (SNP) | VAF 26/127 reads (20%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as rs974995554, COSV56000906; called by muse, mutect2, varscan2
- MCOLN3 | c.1637C>A p.S546Y | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.243); catalogued as rs1211637461, COSV100352741, COSV62013369, COSV62014593; called by muse, mutect2, varscan2
- MED13 | c.4906C>T p.P1636S | Missense Mutation (SNP) | VAF 32/95 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV67262513; called by muse, mutect2, varscan2
- MFSD4A | c.1019C>T p.P340L | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV65656141; called by muse, mutect2, varscan2
- MGAM | c.1537G>A p.E513K | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as rs782373494, COSV72074044, COSV72074183; called by muse, mutect2, varscan2
- MIA3 | c.184C>T p.R62C | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60510777; called by muse, mutect2, varscan2
- MIA3 | c.3644A>G p.Q1215R | Missense Mutation (SNP) | VAF 13/19 reads (68%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.717); catalogued as COSV60510784; called by muse, mutect2, varscan2
- MIP | c.104C>A p.A35D | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.034); catalogued as COSV99234367; called by muse, mutect2, varscan2
- MME | c.814G>A p.E272K | Missense Mutation (SNP) | VAF 36/78 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as COSV64706457; called by muse, mutect2, varscan2
- MME | c.1447C>T p.P483S | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.768); catalogued as rs774711018, COSV64706460, COSV64709533; called by muse, mutect2, varscan2
- MOCS1 | c.1175C>T p.S392F | Missense Mutation (SNP) | VAF 33/57 reads (58%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as rs1404897954, COSV51305242; called by muse, mutect2, varscan2
- MOXD1 | c.469C>T p.P157S | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as COSV60942482; called by muse, mutect2, varscan2
- MREG | c.635C>T p.P212L | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV54373148; called by muse, mutect2, varscan2
- MROH1 | c.133C>T p.R45C | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs772259019, COSV58188133, COSV58188216; called by muse, mutect2, varscan2
- MROH2B | c.3241C>T p.H1081Y | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.37); catalogued as COSV68182210; called by muse, mutect2, varscan2
- MROH2B | c.1647G>A p.W549* | Nonsense Mutation (SNP) | VAF 30/100 reads (30%) | catalogued as COSV68182214, COSV68190008; called by muse, varscan2
- MROH7 | c.3308C>T p.S1103F | Missense Mutation (SNP) | VAF 25/38 reads (66%) | SIFT tolerated (0.25); PolyPhen benign (0.063); catalogued as rs748659707, COSV59868751; called by muse, mutect2, varscan2
- MROH9 | c.859C>T p.H287Y | Missense Mutation (SNP) | VAF 16/105 reads (15%) | SIFT tolerated (0.38); PolyPhen benign (0.011); catalogued as COSV63010437; called by muse, mutect2, varscan2
- MSRB3 | c.521C>T p.T174I | Missense Mutation (SNP) | VAF 38/72 reads (53%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV57588866; called by muse, mutect2, varscan2
- MTHFD2L | c.748C>T p.P250S (on ENST00000395759 / NM_001144978.2; = p.P192S on NM_001004346.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57466455; called by muse, mutect2, varscan2
- MTHFR | c.614G>A p.G205E | Missense Mutation (SNP) | VAF 196/331 reads (59%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1391033297, COSV64877071; called by muse, mutect2, varscan2
- MTMR7 | c.391G>A p.D131N | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs370669270; called by muse, mutect2, varscan2
- MTUS2 | c.79G>A p.E27K | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.341); catalogued as COSV70914890; called by muse, mutect2, varscan2
- MTUS2 | c.3669G>C p.E1223D (on ENST00000612955 / NM_001366650.1; = p.E202D on NM_015233.6) | Missense Mutation (SNP) | VAF 15/24 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV66420467; called by muse, mutect2, varscan2
- MUC16 | c.30046G>A p.E10016K | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.07); catalogued as rs1364835182, COSV67443201; called by muse, mutect2, varscan2
- MUC16 | c.26297C>T p.S8766F | Missense Mutation (SNP) | VAF 35/95 reads (37%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.012); catalogued as COSV67453202; called by muse, mutect2, varscan2
- MUC16 | c.23108C>T p.S7703F | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.935); catalogued as COSV67451909; called by muse, mutect2, varscan2
- MUC16 | c.21944C>A p.S7315Y | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.539); catalogued as COSV67453218, COSV67505816; called by muse, mutect2, varscan2
- MUC16 | c.1333C>T p.P445S | Missense Mutation (SNP) | VAF 67/150 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.029); catalogued as rs777666536, COSV67453248; called by muse, mutect2, varscan2
- MUC17 | c.10490C>T p.S3497L | Missense Mutation (SNP) | VAF 185/471 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV60283081; called by muse, mutect2, varscan2
- MUC20 | c.553C>T p.P185S | Missense Mutation (SNP) | VAF 56/91 reads (62%) | SIFT tolerated, low confidence (0.06); catalogued as COSV100291404, COSV57848339; called by muse, varscan2
- MUC7 | c.941C>T p.S314F | Missense Mutation (SNP) | VAF 149/242 reads (62%) | SIFT tolerated (0.48); PolyPhen benign (0.348); catalogued as COSV59217537; called by muse, mutect2, varscan2
- MUCL3 | c.1333C>T p.P445S (on ENST00000304311; = p.P1321S on NM_080870.4) | Missense Mutation (SNP) | VAF 36/94 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100423859, COSV58516538; called by muse, mutect2, varscan2
- MUSK | c.208C>T p.L70F | Missense Mutation (SNP) | VAF 29/57 reads (51%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.282); catalogued as COSV99504701; called by muse, mutect2, varscan2
- MXRA5 | c.3167T>A p.I1056N | Missense Mutation (SNP) | VAF 46/52 reads (88%) | SIFT tolerated (0.08); PolyPhen benign (0.154); catalogued as COSV54228393; called by muse, mutect2, varscan2
- MYBPH | c.1342G>A p.D448N | Missense Mutation (SNP) | VAF 201/284 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55141716; called by muse, mutect2, varscan2
- MYEF2 | c.1024G>A p.G342R | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV51046564; called by muse, mutect2, varscan2
- MYH11 | c.4444G>A p.E1482K | Missense Mutation (SNP) | VAF 47/108 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV55546598; called by muse, mutect2, varscan2
- MYH13 | c.1685C>T p.S562F | Missense Mutation (SNP) | VAF 48/66 reads (73%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as COSV52822897; called by muse, mutect2, varscan2
- MYH15 | c.5041G>A p.E1681K | Missense Mutation (SNP) | VAF 63/184 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.85); catalogued as COSV56306235, COSV99844400; called by muse, mutect2, varscan2
- MYH2 | c.4144G>A p.E1382K | Missense Mutation (SNP) | VAF 71/110 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55433645; called by muse, mutect2, varscan2
- MYH7 | c.1724C>T p.A575V | Missense Mutation (SNP) | VAF 47/62 reads (76%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.567); catalogued as COSV62517436; called by muse, mutect2, varscan2
- MYO18B | c.1576C>T p.L526F | Missense Mutation (SNP) | VAF 34/73 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV59128814; called by muse, mutect2, varscan2
- MYO18B | c.2548G>A p.E850K | Missense Mutation (SNP) | VAF 42/105 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs775565247, COSV59128820; called by muse, mutect2, varscan2
- MYO18B | c.6464G>A p.S2155N | Missense Mutation (SNP) | VAF 45/115 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.436); catalogued as rs114090829, COSV59127572, COSV59128826; called by muse, mutect2, varscan2
- MYO1F | c.1418G>A p.G473E | Missense Mutation (SNP) | VAF 31/62 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs768444812, COSV100597152, COSV57792840; called by muse, mutect2, varscan2
- MYO3A | c.1327C>T p.L443F | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as COSV56323563, COSV56349644; called by mutect2, varscan2
- MYO5B | c.1549C>T p.P517S | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV99545834; called by muse, mutect2, varscan2
- MYO5B | c.1548C>T p.V516= | Splice Region (SNP) | VAF 24/68 reads (35%) | catalogued as COSV53210064; called by muse, mutect2, varscan2
- MYO7B | c.1423G>A p.E475K | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.615); catalogued as COSV67345629; called by muse, mutect2, varscan2
- MYO7B | c.5150A>T p.Q1717L | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67345643; called by muse, mutect2, varscan2
- MYO9A | c.5701C>T p.R1901W | Missense Mutation (SNP) | VAF 28/51 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765977909, COSV61847850; called by muse, mutect2, varscan2
- MYT1L | c.1420C>T p.P474S | Missense Mutation (SNP) | VAF 39/77 reads (51%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as COSV67710462; called by muse, mutect2, varscan2
- NAB1 | c.814C>T p.H272Y | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61608401; called by muse, mutect2, varscan2
- NAMPT | c.1348C>T p.L450F | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT tolerated (0.71); PolyPhen probably damaging (0.951); catalogued as COSV55994556; called by muse, mutect2, varscan2
- NAT10 | c.275C>T p.P92L | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.321); catalogued as COSV57662856; called by muse, mutect2, varscan2
- NAV3 | c.4154C>T p.S1385F | Missense Mutation (SNP) | VAF 56/94 reads (60%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.687); catalogued as rs1279295428, COSV57068051; called by muse, mutect2, varscan2
- NBEA | c.1510C>T p.P504S | Missense Mutation (SNP) | VAF 58/104 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59768303; called by muse, mutect2, varscan2
- NCAPG | c.1414C>T p.P472S | Missense Mutation (SNP) | VAF 26/38 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV52269219; called by muse, mutect2, varscan2
- NCKAP5 | c.5507G>A p.G1836E | Missense Mutation (SNP) | VAF 97/267 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58433919; called by muse, mutect2, varscan2
- NCKAP5 | c.4858G>A p.E1620K | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58433941; called by muse, mutect2, varscan2
- NCKAP5 | c.2105C>T p.P702L | Missense Mutation (SNP) | VAF 52/122 reads (43%) | SIFT tolerated (0.26); PolyPhen benign (0.006); catalogued as COSV58433946; called by muse, mutect2, varscan2
- NCOA6 | c.773C>T p.P258L | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.011); catalogued as rs1456063536, COSV62862094; called by muse, mutect2, varscan2
- NEB | c.17072A>T p.K5691M | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV50858826, COSV51441536; called by muse, mutect2, varscan2
- NEB | c.13390G>A p.E4464K | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as COSV50859042; called by muse, mutect2
- NEGR1 | c.344C>T p.P115L | Missense Mutation (SNP) | VAF 34/55 reads (62%) | SIFT tolerated (0.33); PolyPhen benign (0.05); catalogued as COSV60834540, COSV60874730; called by muse, mutect2, varscan2
- NEK10 | c.1927C>T p.R643* | Nonsense Mutation (SNP) | VAF 26/58 reads (45%) | catalogued as rs776635841, COSV58281225; called by muse, mutect2, varscan2
- NES | c.3517G>A p.E1173K | Missense Mutation (SNP) | VAF 20/159 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.083); catalogued as COSV63960565; called by muse, mutect2, varscan2
- NETO2 | c.872C>T p.S291F | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.548); catalogued as COSV57451814; called by muse, mutect2
- NFASC | c.2675C>T p.P892L (on ENST00000339876 / NM_001378329.1; = p.P995L on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/132 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.054); catalogued as COSV58361482; called by muse, mutect2, varscan2
- NFATC2 | c.2293T>C p.Y765H | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.959); catalogued as COSV65354026; called by muse, mutect2, varscan2
- NGF | c.145C>T p.R49C | Missense Mutation (SNP) | VAF 57/88 reads (65%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.642); catalogued as rs146716262; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NHSL2 | c.1211C>T p.S404L (on ENST00000510661; = p.S770L on NM_001013627.2) | Missense Mutation (SNP) | VAF 24/25 reads (96%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV65452714; called by muse, mutect2, varscan2
- NIPAL1 | c.606G>A p.M202I | Missense Mutation (SNP) | VAF 46/74 reads (62%) | SIFT tolerated (0.36); PolyPhen benign (0.006); catalogued as COSV55006003; called by muse, mutect2, varscan2
- NLRP10 | c.1909G>A p.E637K | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV60778667; called by muse, mutect2, varscan2
- NLRP10 | c.1060C>T p.P354S | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762414203, COSV60778851; called by muse, mutect2, varscan2
- NLRP11 | c.374C>T p.S125L | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs561555803, COSV64086215; called by muse, mutect2
- NLRP11 | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs866104256, COSV64086222; called by muse, mutect2, varscan2
- NLRP14 | c.2834G>A p.C945Y | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.949); catalogued as rs139902169; called by muse, mutect2
- NLRP14 | c.2836T>G p.C946G | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV55065105; called by muse, mutect2
- NLRP2 | c.2305G>A p.D769N | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.11); catalogued as COSV54753267; called by muse, mutect2, varscan2
- NLRP5 | c.2260C>G p.P754A | Missense Mutation (SNP) | VAF 57/149 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.147); catalogued as COSV66762946; called by muse, mutect2, varscan2
- NLRP9 | c.2908C>T p.P970S | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.346); catalogued as COSV60460927; called by muse, mutect2, varscan2
- NPAP1 | c.260C>T p.A87V | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV61505376; called by muse, mutect2, varscan2
- NPC1L1 | c.1682G>A p.G561E | Missense Mutation (SNP) | VAF 20/108 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.222); catalogued as COSV56923357; called by muse, mutect2, varscan2
- NPHS2 | c.326C>T p.S109F | Missense Mutation (SNP) | VAF 57/66 reads (86%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.642); catalogued as rs267598209, COSV62634835; called by muse, mutect2, varscan2
- NPR2 | c.1297C>T p.P433S | Missense Mutation (SNP) | VAF 25/36 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV61309784; called by muse, mutect2, varscan2
- NR2F2 | c.700C>T p.P234S | Missense Mutation (SNP) | VAF 54/134 reads (40%) | SIFT tolerated (0.15); PolyPhen probably damaging (1); catalogued as COSV67683286; called by muse, mutect2, varscan2
- NR5A2 | c.464C>T p.A155V (on ENST00000367362 / NM_205860.3; = p.A109V on NM_003822.5) | Missense Mutation (SNP) | VAF 55/88 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52646743; called by muse, mutect2, varscan2
- NRAP | c.2371G>A p.E791K (on ENST00000359988 / NM_001322945.2; = p.E756K on NM_006175.4) | Missense Mutation (SNP) | VAF 46/80 reads (58%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.731); catalogued as rs1564728183, COSV63489151; called by muse, mutect2, varscan2
- NRF1 | c.715C>T p.P239S | Missense Mutation (SNP) | VAF 65/183 reads (36%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.932); catalogued as COSV99781995; called by muse, mutect2, varscan2
- NRF1 | c.716C>T p.P239L | Missense Mutation (SNP) | VAF 63/179 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99781997; called by muse, mutect2, varscan2
- NRP2 | c.370T>C p.F124L | Missense Mutation (SNP) | VAF 49/104 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV55925403; called by muse, mutect2, varscan2
- NRXN2 | c.2677A>G p.M893V | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs765465352, COSV55449726; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NSD1 | c.56C>T p.P19L | Missense Mutation (SNP) | VAF 67/133 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.11); catalogued as COSV61772616; called by muse, mutect2, varscan2
- NSD1 | c.328C>T p.P110S | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.115); catalogued as COSV61772623; called by muse, mutect2, varscan2
- NSD2 | c.863G>A p.G288E | Missense Mutation (SNP) | VAF 25/47 reads (53%) | SIFT tolerated (0.88); PolyPhen benign (0.003); catalogued as rs754805178, COSV56388308; called by muse, mutect2, varscan2
- NSUN6 | c.829C>T p.Q277* | Nonsense Mutation (SNP) | VAF 31/43 reads (72%) | catalogued as COSV66032296; called by muse, mutect2, varscan2
- NTRK3 | c.2332G>A p.E778K (on ENST00000360948 / NM_001012338.2; = p.E764K on NM_002530.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/105 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62298607; called by muse, mutect2, varscan2
- NUDT15 | c.157G>A p.G53S | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs199676691, COSV51641899; called by muse, mutect2, varscan2
- NUP98 | c.2524C>T p.R842C | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs995865657, COSV61429918; called by muse, mutect2, varscan2
- NUTM1 | c.1198G>A p.E400K | Missense Mutation (SNP) | VAF 57/124 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.34); catalogued as COSV59216104; called by muse, mutect2, varscan2
- NYAP1 | c.1093G>A p.E365K | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.556); catalogued as COSV55717863; called by muse, varscan2
- NYAP1 | c.1133G>A p.R378Q | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.792); catalogued as rs746070291, COSV55717875; called by muse, varscan2
- OBI1 | c.347A>G p.K116R | Missense Mutation (SNP) | VAF 44/81 reads (54%) | SIFT tolerated (0.05); PolyPhen benign (0.045); catalogued as COSV56144932; called by muse, mutect2, varscan2
- OBSCN | c.15155G>C p.R5052P | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.769); catalogued as COSV52753020; called by muse, mutect2, varscan2
- OBSCN | c.20569C>T p.P6857S | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.058); catalogued as COSV62209421; called by muse, mutect2
- OCIAD2 | c.28C>T p.Q10* | Nonsense Mutation (SNP) | VAF 21/91 reads (23%) | catalogued as COSV56716349; called by muse, mutect2, varscan2
- OPCML | c.149G>A p.G50E | Missense Mutation (SNP) | VAF 40/125 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV59411025; called by muse, mutect2, varscan2
- OPRK1 | c.338C>T p.P113L | Missense Mutation (SNP) | VAF 34/109 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55569041; called by muse, mutect2, varscan2
- OPRPN | c.41C>T p.S14L | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.479); catalogued as COSV68192621; called by muse, mutect2, varscan2
- OR10AD1 | c.28G>A p.E10K | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.197); catalogued as COSV59612411; called by muse, mutect2
- OR10G9 | c.757C>T p.P253S | Missense Mutation (SNP) | VAF 37/109 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV66685947; called by muse, mutect2, varscan2
- OR10K1 | c.53C>T p.S18L | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1406469032, COSV56871035; called by muse, mutect2, varscan2
- OR10X1 | c.938C>T p.A313V | Missense Mutation (SNP) | VAF 21/168 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.42); catalogued as COSV63767113; called by muse, mutect2, varscan2
- OR13D1 | c.543G>A p.W181* | Nonsense Mutation (SNP) | VAF 43/64 reads (67%) | catalogued as rs1291877552, COSV59513635; called by muse, mutect2, varscan2
- OR13H1 | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 67/78 reads (86%) | SIFT deleterious (0.02); PolyPhen benign (0.42); catalogued as COSV58547206; called by muse, mutect2, varscan2
- OR14K1 | c.686G>A p.R229K | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (0.86); PolyPhen benign (0.017); catalogued as COSV99315359; called by muse, mutect2, varscan2
- OR1D2 | c.122G>A p.G41E | Missense Mutation (SNP) | VAF 52/80 reads (65%) | SIFT deleterious (0.01); PolyPhen benign (0.059); catalogued as COSV58921245; called by muse, mutect2, varscan2
- OR1E2 | c.703C>T p.L235F | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT deleterious (0.04); PolyPhen benign (0.35); catalogued as rs1410773982, COSV50265443; called by muse, mutect2, varscan2
- OR1L1 | c.774G>A p.M258I (on ENST00000373686; = p.M208I on NM_001005236.3) | Missense Mutation (SNP) | VAF 55/83 reads (66%) | SIFT tolerated (0.64); PolyPhen benign (0.062); catalogued as COSV58935376; called by muse, mutect2, varscan2
- OR1L6 | c.95G>A p.R32K | Missense Mutation (SNP) | VAF 79/106 reads (75%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as COSV100490955; called by muse, mutect2, varscan2
- OR1L8 | c.551C>T p.P184L | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV59186059; called by muse, mutect2, varscan2
- OR2A25 | c.8G>A p.G3E | Missense Mutation (SNP) | VAF 35/81 reads (43%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs781251490, COSV68716866, COSV68716922; called by muse, mutect2, varscan2
- OR2A25 | c.535G>A p.E179K | Missense Mutation (SNP) | VAF 66/183 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.097); catalogued as COSV68716966; called by muse, mutect2, varscan2
- OR2A25 | c.727C>T p.H243Y | Missense Mutation (SNP) | VAF 28/141 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.778); catalogued as COSV68716972, COSV68717286; called by muse, mutect2, varscan2
- OR2G3 | c.21T>G p.S7R | Missense Mutation (SNP) | VAF 62/74 reads (84%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as COSV60681141; called by muse, mutect2, varscan2
- OR2L3 | c.295C>T p.Q99* | Nonsense Mutation (SNP) | VAF 131/226 reads (58%) | catalogued as COSV63454753; called by muse, mutect2
- OR2L8 | c.295C>T p.Q99* | Nonsense Mutation (SNP) | VAF 27/339 reads (8%) | catalogued as COSV61725991; called by muse, mutect2, varscan2
- OR2M5 | c.517G>A p.E173K | Missense Mutation (SNP) | VAF 227/390 reads (58%) | SIFT tolerated (0.22); PolyPhen benign (0.074); catalogued as COSV63545545, COSV63546003; called by muse, mutect2, varscan2
- OR2T3 | c.293C>T p.S98F | Missense Mutation (SNP) | VAF 48/69 reads (70%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV100613388, COSV62082035; called by muse, mutect2, varscan2
- OR2T34 | c.293C>T p.S98F | Missense Mutation (SNP) | VAF 57/86 reads (66%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV60899954; called by muse, mutect2, varscan2
1,139 further variants in this file (474 protein-altering or splice-affecting, 624 silent, 41 other) are not listed here.
